Somatic mutation profile of tumor specimen C3N-01007-01 (aliquot CPT0095100009) from CPTAC case C3N-01007, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 59.6 years (21,777 days).
Specimen C3N-01007-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 64f0a8c2-ea9f-47d4-a6b7-5c072ec494b6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01007-31 (Blood Derived Normal), aliquot CPT0095120002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/223eabc7-9636-4829-81a3-7e52512a434c

The open-access MAF lists 1,755 somatic variants for this specimen: 1,154 protein-altering or splice-affecting, 420 silent, 181 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,025, Silent 420, Intron 102, Nonsense Mutation 52, Frame Shift Del 33, RNA 23, 3'UTR 23, Splice Region 22, 5'UTR 12, Splice Site 11, 5'Flank 11, Frame Shift Ins 11.

Variants (750 of 1,755; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AR | c.2296G>A p.A766T | Missense Mutation (SNP) | VAF 110/335 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1555996863, CM010766, CM920084, COSV65953780; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.4003C>T p.R1335* | Nonsense Mutation (SNP) | VAF 98/268 reads (37%) | hotspot (GDC flag); catalogued as rs387906846, CM122485, COSV61371872; ClinVar: pathogenic; called by muse, varscan2
- CLCN1 | c.1444G>A p.G482R | Missense Mutation (SNP) | VAF 166/496 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746125212, CM950272, COSV58367156; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.121A>G p.T41A | Missense Mutation (SNP) | VAF 212/605 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs121913412, COSV62687862, COSV62689580, COSV62714770; ClinVar: conflicting interpretations of pathogenicity / pathogenic /  other / likely pathogenic; called by muse, mutect2, varscan2
- CYFIP2 | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 43/138 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as rs1131692231, COSV59037367; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- EIF2B5 | c.569C>T p.T190M (on ENST00000647909; = p.T182M on NM_003907.3) | Missense Mutation (SNP) | VAF 200/555 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs113994053, CM045637; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- ERBB3 | c.310G>A p.V104M | Missense Mutation (SNP) | VAF 149/417 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen possibly damaging (0.64); catalogued as rs1057519893, COSV57246387, COSV57246465, COSV57253558; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ERCC6 | c.2569C>T p.R857* | Nonsense Mutation (SNP) | VAF 129/401 reads (32%) | catalogued as rs751448793, CM083635, CS921181, COSV63392673; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBN1 | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 92/310 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs137854480, CM983861; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FOXP1 | c.1541G>A p.R514H | Missense Mutation (SNP) | VAF 96/256 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs797045586, COSV59537585; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- GCDH | c.481C>T p.R161W | Missense Mutation (SNP) | VAF 237/634 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.949); catalogued as rs1173575355; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KEAP1 | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 143/440 reads (33%) | hotspot (GDC flag); SIFT tolerated (0.19); PolyPhen benign (0.023); catalogued as rs774469695, COSV50262287, COSV50279943; called by muse, mutect2, varscan2
- LDLR | c.1221C>T p.H407= | Silent (SNP) | VAF 82/273 reads (30%) | catalogued as rs778424518, COSV52942267; ClinVar: likely pathogenic / likely benign; called by muse, mutect2, varscan2
- NOTCH1 | c.1393G>A p.A465T | Missense Mutation (SNP) | VAF 157/465 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs1057523819, COSV53030190; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 43/99 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs886042002, CM162636, COSV55873442, COSV55926654, COSV55949642; ClinVar: pathogenic; called by muse, mutect2
- PTEN | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 174/524 reads (33%) | hotspot (GDC flag); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 135/378 reads (36%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- RNF43 | c.433C>T p.R145* | Nonsense Mutation (SNP) | VAF 28/86 reads (33%) | hotspot (GDC flag); catalogued as rs1458799446, COSV68456834; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 266/746 reads (36%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AACS | c.1780G>A p.A594T | Missense Mutation (SNP) | VAF 156/405 reads (39%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs200966429, COSV99907600; called by muse, mutect2, varscan2
- ABCA2 | c.5684C>T p.P1895L (on ENST00000614293; = p.P1865L on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 156/474 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as rs754773302, COSV55805596; called by muse, mutect2, varscan2
- ABCA3 | c.4498C>T p.R1500W | Missense Mutation (SNP) | VAF 105/274 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs969485084, COSV57052117; called by muse, mutect2, varscan2
- ABCC10 | c.3280C>T p.R1094C (on ENST00000372530 / NM_001198934.2; = p.R1066C on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 115/325 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770561160, COSV99766425; called by muse, mutect2, varscan2
- ABCC3 | c.3200G>A p.R1067H | Missense Mutation (SNP) | VAF 112/306 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs751354684, COSV53320177; called by muse, mutect2, varscan2
- ABCC6 | c.3458G>A p.R1153H | Missense Mutation (SNP) | VAF 167/452 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs553479685; called by muse, mutect2, varscan2
- ABCC6 | c.451G>A p.A151T | Missense Mutation (SNP) | VAF 93/344 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1025306917; called by muse, mutect2, varscan2
- ABL1 | c.3359C>T p.S1120L | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.985); catalogued as rs1456042173, COSV59334185; called by muse, mutect2, varscan2
- ABLIM3 | c.929C>T p.A310V | Missense Mutation (SNP) | VAF 98/270 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as rs762942384, COSV58643417; called by muse, varscan2
- ABTB2 | c.2983C>T p.R995C | Missense Mutation (SNP) | VAF 123/368 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as rs746167793; called by muse, mutect2, varscan2
- AC004922.1 | c.1318G>A p.E440K | Missense Mutation (SNP) | VAF 70/237 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs573107646; called by muse, mutect2, varscan2
- AC011005.1 | c.904C>T p.R302C | Missense Mutation (SNP) | VAF 121/323 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as rs1459529513; called by muse, mutect2, varscan2
- AC099489.1 | c.4561C>T p.R1521W | Missense Mutation (SNP) | VAF 52/142 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs761570953; called by muse, mutect2, varscan2
- AC139530.2 | c.186dup p.K63Qfs*118 | Frame Shift Ins (INS) | VAF 37/202 reads (18%) | catalogued as rs769882870; called by mutect2, varscan2
- ACAD9 | c.1675C>T p.R559C | Missense Mutation (SNP) | VAF 114/322 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.614); catalogued as rs138871762; called by muse, mutect2, varscan2
- ACAP3 | c.2030G>A p.R677H | Missense Mutation (SNP) | VAF 78/210 reads (37%) | SIFT tolerated (0.54); PolyPhen benign (0.013); catalogued as rs1236289066; called by muse, varscan2
- ACHE | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs773374235; called by muse, mutect2, varscan2
- ACKR4 | c.563T>C p.F188S | Missense Mutation (SNP) | VAF 92/480 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs1221481797, COSV51442384; called by muse, varscan2
- ACO2 | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 68/195 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV53440971; called by muse, mutect2, varscan2
- ACSBG1 | c.905C>T p.T302M | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.094); catalogued as rs761460593, COSV51904863; called by muse, mutect2, varscan2
- ACTL9 | c.148G>A p.G50S | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.02); catalogued as rs1555753519, COSV61005490; called by muse, mutect2, varscan2
- ACTN1 | c.2452C>T p.R818C | Missense Mutation (SNP) | VAF 116/354 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV51995066, COSV99518920; called by muse, mutect2, varscan2
- ACVR1C | c.1208G>A p.R403Q | Missense Mutation (SNP) | VAF 69/195 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1433923561, COSV54644275; called by muse, mutect2, varscan2
- ADAM12 | c.2480G>A p.R827H | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.579); catalogued as rs767535609; called by muse, mutect2, varscan2
- ADAM12 | c.1152C>T p.T384= | Splice Region (SNP) | VAF 42/108 reads (39%) | catalogued as rs2459114; called by muse, mutect2, varscan2
- ADAM22 | c.1787G>A p.R596Q | Missense Mutation (SNP) | VAF 54/115 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99717796; called by muse, mutect2, varscan2
- ADAM33 | c.332C>T p.T111M | Missense Mutation (SNP) | VAF 57/215 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.143); catalogued as rs146682885, COSV62934385; called by muse, mutect2, varscan2
- ADAMTS1 | c.1954G>A p.V652I | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.337); catalogued as rs201769018, COSV53169152; called by muse, mutect2, varscan2
- ADAMTS16 | c.2422C>T p.R808W | Missense Mutation (SNP) | VAF 156/474 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as rs1380263448, COSV56980181, COSV56991886; called by muse, varscan2
- ADAMTSL1 | c.911C>T p.T304M | Missense Mutation (SNP) | VAF 74/240 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs561847044, COSV52825742; called by muse, mutect2, varscan2
- ADCY8 | c.3280G>A p.G1094S | Missense Mutation (SNP) | VAF 51/130 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1034326187, COSV53895143, COSV53925697; called by muse, mutect2
- ADCY9 | c.883G>A p.G295R | Missense Mutation (SNP) | VAF 99/340 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53576434; called by muse, mutect2, varscan2
- ADGRE5 | c.881C>T p.A294V (on ENST00000242786 / NM_078481.4; = p.A201V on NM_001784.5) | Missense Mutation (SNP) | VAF 93/278 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as COSV54408141; called by muse, mutect2, varscan2
- ADGRL1 | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 70/199 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs202194686, COSV61565410, COSV61566057; called by muse, mutect2, varscan2
- ADGRL2 | c.2428G>A p.V810I (on ENST00000370717 / NM_001366005.1; = p.V797I on NM_012302.4) | Missense Mutation (SNP) | VAF 100/285 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as rs1340238659; called by muse, mutect2, varscan2
- ADGRL3 | c.3728G>A p.R1243H (on ENST00000506720 / NM_001322402.2; = p.R1175H on NM_015236.6) | Missense Mutation (SNP) | VAF 74/204 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746720564; called by muse, mutect2, varscan2
- ADGRL3 | c.4648G>A p.G1550S (on ENST00000506720 / NM_001322402.2; = p.G1439S on NM_015236.6) | Missense Mutation (SNP) | VAF 71/198 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.975); catalogued as rs1032745004, COSV72232386; called by muse, mutect2, varscan2
- ADNP2 | c.3145C>T p.R1049C | Missense Mutation (SNP) | VAF 102/290 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.301); catalogued as rs769643353, COSV51541102; called by muse, mutect2, varscan2
- AFF3 | c.2783G>T p.G928V | Missense Mutation (SNP) | VAF 105/277 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.691); catalogued as COSV100419214; called by muse, mutect2, varscan2
- AGGF1 | c.52C>A p.P18T | Missense Mutation (SNP) | VAF 112/310 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.026); catalogued as COSV57228790; called by muse, mutect2, varscan2
- AGRN | c.1255G>A p.V419I | Missense Mutation (SNP) | VAF 30/320 reads (9%) | SIFT tolerated (0.83); PolyPhen benign (0.203); catalogued as rs758479799; called by muse, mutect2
- AHDC1 | c.1157G>A p.R386H | Missense Mutation (SNP) | VAF 57/166 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as rs539332275; called by muse, mutect2, varscan2
- AIDA | c.803C>A p.P268H | Missense Mutation (SNP) | VAF 77/231 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.566); catalogued as COSV60514602; called by muse, mutect2, varscan2
- AKAP17A | c.338G>A p.R113H | Missense Mutation (SNP) | VAF 67/167 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.972); catalogued as rs767031850, COSV100001751; called by muse, mutect2, varscan2
- AKAP8L | c.1348G>A p.V450M | Missense Mutation (SNP) | VAF 109/352 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.139); catalogued as rs780547911; called by muse, mutect2, varscan2
- ALKBH3 | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 146/377 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776707628, COSV100236314, COSV57025074; called by muse, mutect2, varscan2
- AMER2 | c.1618G>A p.G540R | Missense Mutation (SNP) | VAF 46/144 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.044); catalogued as rs1566015166, COSV100766110; called by muse, mutect2, varscan2
- AMER2 | c.1468C>T p.R490C | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.973); catalogued as COSV63441571; called by muse, mutect2, varscan2
- ANKRD1 | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 169/496 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as rs758588912, COSV100865301; called by muse, mutect2, varscan2
- ANKRD20A5P | n.201C>T | Splice Region (SNP) | VAF 44/144 reads (31%) | catalogued as rs767838063; called by muse, mutect2
- ANKRD36C | c.3155G>A p.R1052H | Missense Mutation (SNP) | VAF 82/291 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.276); catalogued as rs774459798; called by muse, mutect2, varscan2
- ANKRD49 | c.428C>T p.T143M | Missense Mutation (SNP) | VAF 165/450 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.85); catalogued as rs1250295325, COSV57059873; called by muse, mutect2, varscan2
- ANPEP | c.1726C>T p.R576C | Missense Mutation (SNP) | VAF 46/151 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs746685166, COSV100263011; called by muse, mutect2, varscan2
- ANXA10 | c.578C>T p.T193I | Missense Mutation (SNP) | VAF 73/225 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.326); catalogued as rs1011098202, COSV63738096; called by muse, mutect2, varscan2
- AP4M1 | c.712A>G p.K238E | Missense Mutation (SNP) | VAF 277/804 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.189); catalogued as rs1309559726; called by muse, mutect2, varscan2
- AP5Z1 | c.2096C>T p.T699I | Missense Mutation (SNP) | VAF 58/168 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as rs772195008, COSV62244113; called by muse, mutect2, varscan2
- APBA1 | c.959C>T p.A320V | Missense Mutation (SNP) | VAF 47/99 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs758915812; called by muse, mutect2, varscan2
- APOA4 | c.460C>T p.R154W | Missense Mutation (SNP) | VAF 64/161 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs150633651; called by muse, mutect2, varscan2
- AR | c.1249G>A p.A417T | Missense Mutation (SNP) | VAF 73/173 reads (42%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as COSV65957564; called by muse, mutect2, varscan2
- ARAP1 | c.3814C>T p.R1272C (on ENST00000393609 / NM_001040118.2; = p.R1027C on NM_015242.4) | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs1565210158; called by muse, mutect2, varscan2
- ARFGEF1 | c.4000G>A p.A1334T | Missense Mutation (SNP) | VAF 71/251 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.066); catalogued as COSV51617778; called by muse, mutect2, varscan2
- ARHGAP11A | c.1202G>A p.R401Q | Missense Mutation (SNP) | VAF 75/188 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs780760500; called by muse, varscan2
- ARHGAP30 | c.910C>T p.R304C | Missense Mutation (SNP) | VAF 97/331 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs911473430, COSV63516348; called by muse, mutect2, varscan2
- ARHGAP36 | c.1247G>A p.R416H | Missense Mutation (SNP) | VAF 76/202 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs759041751, COSV52267857; called by muse, mutect2, varscan2
- ARHGAP39 | c.2407C>T p.R803C | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); catalogued as rs1428420898, COSV52767542; called by muse, mutect2, varscan2
- ARHGAP42 | c.1012C>T p.R338* | Nonsense Mutation (SNP) | VAF 38/178 reads (21%) | catalogued as rs1284153052; called by muse, mutect2
- ARHGEF18 | c.742C>T p.R248C (on ENST00000359920 / NM_001130955.2; = p.R144C on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 124/377 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.081); catalogued as rs764885531; called by muse, mutect2, varscan2
- ARHGEF18 | c.2246G>A p.R749Q (on ENST00000359920 / NM_001130955.2; = p.R645Q on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.282); catalogued as rs150543189; called by muse, mutect2, varscan2
- ARHGEF2 | c.506G>A p.R169Q (on ENST00000361247 / NM_001162383.2; = p.R142Q on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 106/329 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs1346859914, COSV58110562; called by muse, mutect2, varscan2
- ARID3C | c.568C>T p.R190C | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs758739197, COSV52406349; called by muse, mutect2, varscan2
- ARL14 | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 80/203 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.283); catalogued as rs749857278; called by muse, mutect2, varscan2
- ARPP21 | c.1964G>A p.R655Q | Missense Mutation (SNP) | VAF 106/306 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs761270285, COSV51800417; called by muse, mutect2, varscan2
- ASB12 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 204/593 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as rs759793264; called by muse, mutect2, varscan2
- ASPM | c.2993C>T p.P998L | Missense Mutation (SNP) | VAF 156/494 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs971453990, COSV54129320; called by muse, varscan2
- ATP13A4 | c.1322C>T p.A441V | Missense Mutation (SNP) | VAF 79/219 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.615); catalogued as rs148750067; called by muse, mutect2, varscan2
- ATP5MC2 | c.68G>A p.R23H | Missense Mutation (SNP) | VAF 84/255 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs566625928, COSV58601689; called by muse, mutect2, varscan2
- ATP5PD | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 70/218 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.029); catalogued as rs149411955, COSV104399310, COSV56902592; called by muse, mutect2
- ATRN | c.215T>C p.L72P | Missense Mutation (SNP) | VAF 55/181 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1039364929, COSV99496944; called by muse, mutect2, varscan2
- AXIN1 | c.716C>T p.P239L | Missense Mutation (SNP) | VAF 135/335 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768412292, COSV99249489; called by muse, mutect2, varscan2
- BABAM2 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 72/239 reads (30%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.922); catalogued as rs528903527; called by muse, varscan2
- BAG6 | c.3482G>A p.R1161H (on ENST00000676571; = p.R1114H on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/211 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.06); catalogued as rs141179629; called by muse, mutect2, varscan2
- BAHCC1 | c.5624C>T p.S1875L | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs1225360507; called by muse, mutect2, varscan2
- BAIAP3 | c.2020C>T p.R674C | Missense Mutation (SNP) | VAF 74/222 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs756410804; called by muse, varscan2
- BCAR3 | c.1783C>T p.R595C | Missense Mutation (SNP) | VAF 92/253 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776773073; called by muse, mutect2, varscan2
- BCDIN3D | c.725A>G p.H242R | Missense Mutation (SNP) | VAF 96/250 reads (38%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.915); catalogued as rs759969761; called by muse, varscan2
- BCOR | c.2243G>A p.R748Q | Missense Mutation (SNP) | VAF 189/512 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); catalogued as rs771287230; called by mutect2, varscan2
- BDH1 | c.780G>A p.M260I | Missense Mutation (SNP) | VAF 103/314 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.074); catalogued as COSV104420054; called by muse, mutect2, varscan2
- BICRA | c.3425C>T p.T1142M | Missense Mutation (SNP) | VAF 94/309 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1446116977; called by muse, mutect2, varscan2
- BLOC1S1 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 59/230 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.076); catalogued as rs771492578; called by muse, mutect2, varscan2
- BMP1 | c.2519G>A p.R840H | Missense Mutation (SNP) | VAF 104/315 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.298); catalogued as rs145359380; called by muse, mutect2, varscan2
- BNC2 | c.2624G>A p.R875H | Missense Mutation (SNP) | VAF 139/395 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs565215420, COSV66147924; called by muse, mutect2, varscan2
- BPGM | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 63/162 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs372950660; called by muse, mutect2, varscan2
- BPIFC | c.1149C>T p.F383= | Splice Region (SNP) | VAF 38/121 reads (31%) | catalogued as rs200868839, COSV55910552; called by muse, mutect2
- BRCA2 | c.7006C>T p.R2336C | Missense Mutation (SNP) | VAF 66/223 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs431825347, COSV66448051; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- BRD7 | c.1709C>T p.P570L | Missense Mutation (SNP) | VAF 47/127 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs772936465, COSV54271736; called by muse, mutect2, varscan2
- C10orf71 | c.3946G>A p.E1316K | Missense Mutation (SNP) | VAF 82/211 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.429); catalogued as rs1438668932, COSV60506011, COSV60506026; called by muse, mutect2, varscan2
- C11orf95 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58311326; called by muse, mutect2, varscan2
- C12orf65 | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 210/508 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.467); catalogued as rs777262448, COSV99473869; called by muse, varscan2
- C14orf132 | c.322G>A p.V108M (on ENST00000553782 / NM_001289139.2; = p.V77M on NM_001252507.3) | Missense Mutation (SNP) | VAF 78/214 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs145994650; called by muse, varscan2
- C16orf71 | c.1144C>T p.R382W | Missense Mutation (SNP) | VAF 65/209 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs147266014; called by muse, mutect2, varscan2
- C1QTNF3 | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 62/154 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as rs971247603; called by muse, varscan2
- C3orf20 | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 80/236 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.365); catalogued as rs370846039; called by muse, mutect2, varscan2
- CABLES2 | c.932C>T p.P311L | Missense Mutation (SNP) | VAF 79/228 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758418477; called by muse, mutect2, varscan2
- CACNA1A | c.3095G>T p.R1032M | Missense Mutation (SNP) | VAF 22/344 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs865977540; called by muse, mutect2
- CACNA1A | c.1117C>T p.R373W | Missense Mutation (SNP) | VAF 90/209 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1244976416; called by muse, mutect2, varscan2
- CACNA1C | c.296G>A p.R99H | Missense Mutation (SNP) | VAF 105/325 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV59735896; called by muse, mutect2, varscan2
- CACNA2D2 | c.1217G>A p.R406H | Missense Mutation (SNP) | VAF 96/330 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs752852530; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CALB2 | c.574-1G>A p.X192_splice | Splice Site (SNP) | VAF 54/161 reads (34%) | catalogued as COSV56939250; called by muse, mutect2, varscan2
- CALHM3 | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 115/319 reads (36%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as rs752823036; called by muse, mutect2, varscan2
- CALY | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 91/437 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1564785687; called by muse, mutect2, varscan2
- CAMK2A | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 54/155 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs779607303; called by muse, mutect2, varscan2
- CAMSAP3 | c.2368C>T p.R790W | Missense Mutation (SNP) | VAF 47/125 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV50383967; called by muse, mutect2, varscan2
- CAMTA1 | c.3275C>T p.A1092V | Missense Mutation (SNP) | VAF 84/257 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.911); catalogued as rs771571157, COSV57894095; called by muse, mutect2, varscan2
- CAND2 | c.1214G>A p.R405Q (on ENST00000456430 / NM_001162499.2; = p.R312Q on NM_012298.3) | Missense Mutation (SNP) | VAF 109/306 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as rs781329525, COSV55993341; called by muse, mutect2
- CAPN14 | c.225G>A p.P75= | Splice Region (SNP) | VAF 72/213 reads (34%) | catalogued as rs758048372; called by muse, mutect2, varscan2
- CAPN15 | c.2579G>A p.G860D | Missense Mutation (SNP) | VAF 151/455 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.621); catalogued as rs1406865316; called by muse, mutect2, varscan2
- CASTOR2 | c.253G>A p.G85S | Missense Mutation (SNP) | VAF 170/522 reads (33%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); catalogued as rs1188054003; called by muse, mutect2, varscan2
- CATSPERG | c.3280G>A p.V1094M | Missense Mutation (SNP) | VAF 143/388 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs757579145; called by muse, mutect2, varscan2
- CBR4 | c.635C>T p.A212V | Missense Mutation (SNP) | VAF 67/205 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.306); catalogued as rs774609370; called by muse, mutect2, varscan2
- CBX2 | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 133/380 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1555830284; called by muse, mutect2, varscan2
- CCDC137 | c.508C>T p.R170W | Missense Mutation (SNP) | VAF 77/298 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs184068585, COSV61303299; called by muse, mutect2
- CCDC166 | c.1196C>T p.T399M | Missense Mutation (SNP) | VAF 62/207 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.216); catalogued as rs1554616603, COSV101545854; called by muse, mutect2, varscan2
- CCDC40 | c.1525C>T p.R509C | Missense Mutation (SNP) | VAF 210/585 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749901313, COSV53901215, COSV53905198, COSV99481502; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC74A | c.838C>T p.R280C | Missense Mutation (SNP) | VAF 32/258 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs774819631, COSV54609281; called by muse, mutect2, varscan2
- CCDC74B | c.838C>T p.R280C | Missense Mutation (SNP) | VAF 60/357 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs750987487, COSV60100597; called by muse, mutect2, varscan2
- CCSER1 | c.1840G>A p.G614R | Missense Mutation (SNP) | VAF 101/428 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs769520893; called by muse, mutect2, varscan2
- CD207 | c.934G>A p.D312N | Missense Mutation (SNP) | VAF 47/257 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV101338534; called by muse, mutect2, varscan2
- CD2BP2 | c.422C>T p.S141L | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.644); catalogued as rs771942416; called by muse, mutect2, varscan2
- CD34 | c.410G>A p.S137N | Missense Mutation (SNP) | VAF 148/491 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as rs1374426521; called by muse, mutect2, varscan2
- CDHR4 | c.863G>A p.R288Q | Missense Mutation (SNP) | VAF 68/200 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as rs747880395; called by muse, mutect2, varscan2
- CDK15 | c.529G>A p.V177I (on ENST00000652192 / NM_001366386.2; = p.V126I on NM_139158.2) | Missense Mutation (SNP) | VAF 70/198 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs199511628; called by muse, mutect2, varscan2
- CDKN2B | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 136/425 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.542); catalogued as rs751427195, COSV52805423; called by muse, mutect2, varscan2
- CDX1 | c.91G>A p.G31S | Missense Mutation (SNP) | VAF 39/141 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0.066); catalogued as rs757763760; called by muse, mutect2, varscan2
- CEACAM7 | c.295C>T p.R99* | Nonsense Mutation (SNP) | VAF 29/93 reads (31%) | catalogued as rs150543831; called by muse, mutect2, varscan2
- CELSR2 | c.7102C>T p.R2368W | Missense Mutation (SNP) | VAF 88/225 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780226633, COSV54778718; called by muse, mutect2, varscan2
- CELSR3 | c.4258C>T p.R1420C | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50843673; called by muse, mutect2, varscan2
- CEP170B | c.2998G>A p.A1000T (on ENST00000453495; = p.A929T on NM_015005.3) | Missense Mutation (SNP) | VAF 60/186 reads (32%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as rs1306339389; called by muse, mutect2, varscan2
- CFAP43 | c.3791G>A p.R1264Q | Missense Mutation (SNP) | VAF 72/256 reads (28%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as rs754109266, COSV63852814; called by muse, mutect2, varscan2
- CFAP47 | c.7158G>A p.T2386= | Splice Region (SNP) | VAF 21/70 reads (30%) | catalogued as rs1569296203; called by muse, mutect2, varscan2
- CFAP65 | c.4148C>T p.T1383M | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.035); catalogued as rs375883960, COSV58560516; called by muse, mutect2, varscan2
- CFAP69 | c.571G>A p.A191T | Missense Mutation (SNP) | VAF 80/205 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.23); catalogued as rs1342965565; called by muse, mutect2, varscan2
- CHCHD3 | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 76/205 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as rs558477829, COSV52777943; called by muse, mutect2, varscan2
- CHD3 | c.3358G>A p.D1120N | Missense Mutation (SNP) | VAF 54/112 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1350258866, COSV100391711; called by muse, mutect2, varscan2
- CHD6 | c.1960G>A p.A654T | Missense Mutation (SNP) | VAF 71/199 reads (36%) | SIFT tolerated (0.95); PolyPhen benign (0.091); catalogued as rs773310573; called by muse, mutect2, varscan2
- CHD7 | c.5441C>T p.A1814V | Missense Mutation (SNP) | VAF 71/171 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.107); catalogued as COSV71113522; called by muse, mutect2, varscan2
- CHRD | c.203T>C p.L68P | Missense Mutation (SNP) | VAF 58/169 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52613385; called by muse, mutect2, varscan2
- CHRNG | c.829G>A p.A277T | Missense Mutation (SNP) | VAF 243/678 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.389); catalogued as rs750265817, COSV67315562; called by muse, mutect2, varscan2
- CHST3 | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 89/242 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64151842; called by muse, mutect2, varscan2
- CIAO2B | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 76/256 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs1211114512; called by muse, mutect2, varscan2
- CIITA | c.2698C>T p.Q900* | Nonsense Mutation (SNP) | VAF 162/484 reads (33%) | catalogued as rs573523090; called by muse, mutect2, varscan2
- CLCN4 | c.1051C>T p.R351C | Missense Mutation (SNP) | VAF 56/163 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs763535956; called by muse, mutect2, varscan2
- CLEC3A | c.577C>T p.R193C (on ENST00000651443; = p.R184C on NM_005752.6) | Missense Mutation (SNP) | VAF 90/206 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as rs761179747, COSV100222086; called by muse, mutect2
- CLIC2 | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 115/352 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1032630286, COSV58935736; called by muse, mutect2, varscan2
- CLK2 | c.361C>T p.R121W | Missense Mutation (SNP) | VAF 172/436 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs771750477, COSV62878063; called by muse, mutect2, varscan2
- CLUH | c.757G>A p.A253T (on ENST00000435359; = p.A291T on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 83/229 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs771924837; called by muse, mutect2, varscan2
- CNOT4 | c.1513C>T p.R505C (on ENST00000315544 / NM_001190848.1; = p.R502C on NM_013316.4) | Missense Mutation (SNP) | VAF 125/346 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs1381518139; called by muse, mutect2, varscan2
- CNTROB | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 109/338 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs374604826; called by muse, mutect2, varscan2
- COBL | c.3473G>A p.R1158H | Missense Mutation (SNP) | VAF 91/215 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140694702; called by muse, mutect2, varscan2
- COL11A2 | c.1559G>A p.G520D (on ENST00000341947 / NM_080680.3; = p.G413D on NM_080679.2) | Missense Mutation (SNP) | VAF 79/219 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100553371; called by muse, mutect2, varscan2
- COL5A3 | c.1144G>A p.A382T | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs868272221, COSV53420063; called by muse, mutect2, varscan2
- COL6A5 | c.5215C>T p.R1739W | Missense Mutation (SNP) | VAF 122/374 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as rs752943906; called by muse, mutect2, varscan2
- CPLX3 | c.95C>T p.S32L | Missense Mutation (SNP) | VAF 119/332 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.39); catalogued as COSV59002363, COSV59003859; called by muse, mutect2, varscan2
- CPXM2 | c.2242C>T p.R748W | Missense Mutation (SNP) | VAF 88/252 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs1455207884, COSV53867011, COSV53869728; called by muse, mutect2, varscan2
- CPXM2 | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.56); catalogued as rs758287087; called by muse, mutect2, varscan2
- CRACD | c.559G>A p.G187S | Missense Mutation (SNP) | VAF 48/184 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV99073089, COSV99949491; called by muse, mutect2
- CRACD | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 125/377 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs373287876; called by muse, mutect2, varscan2
- CRB2 | c.2548G>A p.G850S | Missense Mutation (SNP) | VAF 61/141 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs765067093; called by muse, mutect2, varscan2
- CRTAM | c.82G>A p.V28M | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs774319057; called by muse, mutect2, varscan2
- CSMD1 | c.8024G>A p.R2675Q (on ENST00000520002; = p.R2674Q on NM_033225.6) | Missense Mutation (SNP) | VAF 47/132 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.027); catalogued as rs775089714, COSV100153884, COSV59332663; called by muse, mutect2
- CTSF | c.1223G>A p.G408D | Missense Mutation (SNP) | VAF 82/216 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.231); catalogued as COSV59747388; called by muse, mutect2, varscan2
- CTU2 | c.571G>A p.G191R | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT tolerated (0.62); PolyPhen benign (0.057); catalogued as rs374137025; called by muse, mutect2, varscan2
- CUX1 | c.2932G>A p.V978I | Missense Mutation (SNP) | VAF 71/186 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV52896344; called by muse, mutect2, varscan2
- CWF19L2 | c.1946G>A p.R649H | Missense Mutation (SNP) | VAF 119/397 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs774777965, COSV56515466; called by muse, mutect2, varscan2
- CYP2A13 | c.1309C>T p.R437W | Missense Mutation (SNP) | VAF 56/180 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs559504306, COSV57839616; called by muse, mutect2, varscan2
- CYP2A6 | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 64/219 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.692); catalogued as rs375051929; called by muse, mutect2, varscan2
- CYP3A7 | c.1312G>A p.G438R | Missense Mutation (SNP) | VAF 142/389 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60483731; called by muse, mutect2, varscan2
- CYP4F3 | c.1094G>A p.R365H | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.192); catalogued as rs573278241; called by muse, mutect2, varscan2
- CYP51A1 | c.1026dup p.C343Mfs*19 | Frame Shift Ins (INS) | VAF 48/156 reads (31%) | catalogued as rs746385504; called by mutect2, varscan2
- CYSRT1 | c.448C>T p.R150C (on ENST00000409414; = p.R110C on NM_199001.5) | Missense Mutation (SNP) | VAF 87/257 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.013); catalogued as rs1412302436; called by muse, varscan2
- DAG1 | c.2035C>T p.R679C | Missense Mutation (SNP) | VAF 75/204 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); catalogued as rs778608269; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DCAF13 | c.1096C>T p.R366* | Nonsense Mutation (SNP) | VAF 40/118 reads (34%) | catalogued as rs375018347; called by muse, mutect2
- DCANP1 | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 75/207 reads (36%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs112827541; called by muse, mutect2, varscan2
- DCLK3 | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 110/327 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs181512442; called by muse, mutect2, varscan2
- DDI2 | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs920969914; called by muse, mutect2
- DDR1 | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 98/268 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1477583730, COSV61324964; called by muse, mutect2, varscan2
- DDR1 | c.663C>T p.G221= | Splice Region (SNP) | VAF 66/183 reads (36%) | catalogued as rs773211020, COSV61320414; called by muse, varscan2
- DDX39A | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 78/203 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as rs775269512, COSV54390780; called by muse, mutect2, varscan2
- DDX5 | c.440_441+2del p.X147_splice | Splice Site (DEL) | VAF 67/193 reads (35%) | catalogued as rs782442161; called by mutect2, pindel, varscan2
- DDX54 | c.1076C>T p.T359M | Missense Mutation (SNP) | VAF 93/260 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.067); catalogued as rs549423905, COSV100013903; called by muse, mutect2, varscan2
- DELE1 | c.277G>A p.V93M | Missense Mutation (SNP) | VAF 62/152 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs769560236; called by muse, mutect2, varscan2
- DENND2B | c.1294C>T p.R432W | Missense Mutation (SNP) | VAF 69/197 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as rs550077325; called by muse, mutect2, varscan2
- DEPDC5 | c.2600G>A p.R867H (on ENST00000400246; = p.R936H on NM_014662.5) | Missense Mutation (SNP) | VAF 90/271 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772897391, COSV56692710; called by muse, mutect2, varscan2
- DIAPH3 | c.958del p.I320Lfs*20 (on ENST00000400324 / NM_001042517.2; = p.I57Lfs*20 on NM_030932.3) | Frame Shift Del (DEL) | VAF 57/171 reads (33%) | catalogued as rs755069320; called by mutect2, varscan2
- DIP2B | c.3578G>A p.R1193Q | Missense Mutation (SNP) | VAF 86/248 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs748825270; called by muse, mutect2, varscan2
- DLK1 | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs770804393, COSV57992280; called by muse, varscan2
- DLK1 | c.799C>T p.R267C | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as rs774427009, COSV57990680; called by muse, varscan2
- DLL4 | c.1715C>T p.S572L | Missense Mutation (SNP) | VAF 166/424 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.509); catalogued as rs771978335, COSV51061026; called by muse, mutect2, varscan2
- DNAH2 | c.12781G>A p.V4261M | Missense Mutation (SNP) | VAF 138/349 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs769092944, COSV66721410; called by muse, mutect2, varscan2
- DNAH5 | c.13285C>T p.R4429* | Nonsense Mutation (SNP) | VAF 221/669 reads (33%) | catalogued as COSV54229483; called by muse, mutect2, varscan2
- DNHD1 | c.10375C>T p.R3459C | Missense Mutation (SNP) | VAF 57/155 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.913); catalogued as rs552630821, COSV54435183; called by muse, mutect2, varscan2
- DNM2 | c.595C>T p.R199W | Missense Mutation (SNP) | VAF 75/468 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1415171157, COSV58961222; called by muse, mutect2, varscan2
- DNM3 | c.1627G>A p.G543S (on ENST00000355305 / NM_001350206.2; = p.G533S on NM_015569.5) | Missense Mutation (SNP) | VAF 133/358 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs570667502; called by muse, mutect2, varscan2
- DNMT1 | c.3913G>A p.G1305S | Missense Mutation (SNP) | VAF 49/141 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1197552228; called by muse, mutect2, varscan2
- DNMT3A | c.337G>A p.G113R | Missense Mutation (SNP) | VAF 40/245 reads (16%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.98); catalogued as rs758151481, COSV53061443; called by muse, mutect2, varscan2
- DOCK3 | c.3866G>T p.R1289L | Missense Mutation (SNP) | VAF 64/184 reads (35%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs539996527; called by muse, varscan2
- DOCK6 | c.409G>A p.V137I | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs760454261, COSV99625148; called by muse, mutect2, varscan2
- DOK2 | c.1057G>A p.A353T | Missense Mutation (SNP) | VAF 26/178 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.01); catalogued as rs1363527759; called by muse, mutect2
- DPP3 | c.373C>T p.R125W | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.428); catalogued as rs145463220, COSV64756069; called by muse, mutect2, varscan2
- DPPA3 | c.461C>T p.T154I | Missense Mutation (SNP) | VAF 73/224 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.1); catalogued as rs1383658690; called by muse, mutect2, varscan2
- DRG2 | c.1084G>A p.V362M | Missense Mutation (SNP) | VAF 73/233 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.176); catalogued as rs776260806; called by muse, mutect2, varscan2
- DSC3 | c.2377C>T p.R793W | Missense Mutation (SNP) | VAF 154/482 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.104); catalogued as rs369025868; called by muse, mutect2, varscan2
- DST | c.7142C>T p.T2381M | Missense Mutation (SNP) | VAF 94/276 reads (34%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.082); catalogued as rs764753913; called by muse, mutect2, varscan2
- DYNC1H1 | c.7565C>T p.T2522M | Missense Mutation (SNP) | VAF 201/607 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs528647293; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ECI1 | c.441C>T p.N147= | Splice Region (SNP) | VAF 125/356 reads (35%) | catalogued as rs778709886; called by muse, mutect2, varscan2
- EDA | c.1000C>T p.R334C | Missense Mutation (SNP) | VAF 106/302 reads (35%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.169); catalogued as rs757610457, CD042590; called by muse, mutect2, varscan2
- EDAR | c.29C>T p.T10M | Missense Mutation (SNP) | VAF 112/348 reads (32%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as rs777888641, COSV51506041; called by muse, mutect2, varscan2
- EFS | c.466C>T p.R156W | Missense Mutation (SNP) | VAF 64/145 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as rs1350003689; called by muse, mutect2, varscan2
- EHBP1L1 | c.3511G>A p.D1171N | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.273); catalogued as COSV58573262; called by muse, mutect2, varscan2
- EHD2 | c.754G>A p.V252I | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767063664, COSV54406532; called by muse, varscan2
- EIF2AK3 | c.2737G>A p.V913M | Missense Mutation (SNP) | VAF 151/511 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as rs761829897; called by muse, mutect2, varscan2
- EIF2D | c.1238C>T p.T413M | Missense Mutation (SNP) | VAF 89/267 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs369659631; called by muse, mutect2, varscan2
- ELFN2 | c.1390G>A p.V464M | Missense Mutation (SNP) | VAF 107/259 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.365); catalogued as rs1163411535, COSV68746642; called by muse, mutect2, varscan2
- ELFN2 | c.689G>A p.R230Q | Missense Mutation (SNP) | VAF 109/288 reads (38%) | SIFT tolerated (0.68); PolyPhen benign (0.287); catalogued as rs760630459; called by muse, mutect2, varscan2
- ELOA | c.1394del p.N465Mfs*19 | Frame Shift Del (DEL) | VAF 92/303 reads (30%) | catalogued as rs766700925; called by mutect2, varscan2
- ELOA2 | c.20C>T p.T7M | Missense Mutation (SNP) | VAF 152/439 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as rs572647337, COSV55296268; called by muse, mutect2, varscan2
- EMSY | c.2518C>T p.R840C | Missense Mutation (SNP) | VAF 68/251 reads (27%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs763429690, COSV58257614; called by muse, varscan2
- EP300 | c.5818C>T p.R1940C | Missense Mutation (SNP) | VAF 169/486 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV54349443; called by muse, mutect2, varscan2
- EPHB4 | c.2065G>A p.V689I | Missense Mutation (SNP) | VAF 81/225 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs529340542, COSV62268831; called by muse, mutect2, varscan2
- EPS8 | c.1967G>A p.R656H | Missense Mutation (SNP) | VAF 137/449 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.635); catalogued as rs149793749; called by muse, mutect2, varscan2
- ERBB3 | c.3448G>A p.G1150R | Missense Mutation (SNP) | VAF 110/302 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV99916622, COSV99918114; called by muse, mutect2, varscan2
- ERC2 | c.2522G>A p.R841Q | Missense Mutation (SNP) | VAF 66/215 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs772063893, COSV55636646; called by muse, mutect2, varscan2
- ERICH5 | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 89/274 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.077); catalogued as rs146451719; called by muse, mutect2, varscan2
- ERMARD | c.557G>A p.R186H | Missense Mutation (SNP) | VAF 99/266 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779208498; called by muse, mutect2, varscan2
- ERN1 | c.842+1G>A p.X281_splice | Splice Site (SNP) | VAF 69/161 reads (43%) | catalogued as rs1374944834; called by muse, mutect2, varscan2
- ERP29 | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 84/277 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.187); catalogued as rs746390284; called by muse, mutect2, varscan2
- EVPL | c.1789C>T p.R597W | Missense Mutation (SNP) | VAF 107/276 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs762605470; called by muse, mutect2, varscan2
- EVX1 | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 113/348 reads (32%) | SIFT tolerated (0.46); PolyPhen benign (0.124); catalogued as rs377423519; called by muse, mutect2, varscan2
- EXD2 | c.1475G>A p.R492H (on ENST00000312994 / NM_001193362.1; = p.R367H on NM_018199.3) | Missense Mutation (SNP) | VAF 139/376 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs769852607, COSV57282908; called by muse, mutect2, varscan2
- EXOC3L2 | c.1672C>T p.R558W | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs764394851; called by muse, mutect2, varscan2
- EXOC4 | c.715C>T p.R239* | Nonsense Mutation (SNP) | VAF 70/265 reads (26%) | catalogued as rs781478736; called by muse, mutect2, varscan2
- EXOSC7 | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 62/191 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1353267368; called by muse, varscan2
- EXTL1 | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 64/161 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as rs375069374; called by muse, mutect2, varscan2
- EYS | c.5395A>G p.T1799A | Missense Mutation (SNP) | VAF 133/381 reads (35%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.005); catalogued as rs144694451; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- F5 | c.2542C>T p.R848C | Missense Mutation (SNP) | VAF 87/226 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.118); catalogued as rs375248946; called by muse, mutect2, varscan2
- FAAP100 | c.2302G>A p.V768I | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as rs767477547, COSV59886091; called by muse, mutect2, varscan2
- FAM110B | c.503C>T p.T168M | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.277); catalogued as rs776004086, COSV64067131; called by muse, mutect2, varscan2
- FAM13C | c.241C>T p.R81* | Nonsense Mutation (SNP) | VAF 125/384 reads (33%) | catalogued as rs993269695; called by muse, mutect2, varscan2
- FAM166A | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 56/170 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.082); catalogued as rs770828085, COSV100457680; called by muse, mutect2, varscan2
- FAM47B | c.1532G>A p.G511D | Missense Mutation (SNP) | VAF 83/228 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV61452243, COSV61457311; called by muse, mutect2, varscan2
- FAM47C | c.1172G>A p.R391H | Missense Mutation (SNP) | VAF 153/386 reads (40%) | SIFT tolerated (1); PolyPhen possibly damaging (0.664); catalogued as rs782247630, COSV63727798; called by muse, mutect2, varscan2
- FARP1 | c.2690G>A p.R897H | Missense Mutation (SNP) | VAF 75/235 reads (32%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.8); catalogued as rs1157099768, COSV60333628; called by muse, mutect2
- FAT1 | c.11597C>T p.A3866V | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs781093382, COSV71676338; called by muse, mutect2, varscan2
- FBXL18 | c.1670G>A p.C557Y | Missense Mutation (SNP) | VAF 76/249 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1316599473; called by muse, mutect2, varscan2
- FBXO25 | c.926C>T p.A309V (on ENST00000382824 / NM_183421.2; = p.A242V on NM_012173.3) | Missense Mutation (SNP) | VAF 145/378 reads (38%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs754469354; called by muse, mutect2, varscan2
- FBXO40 | c.1577G>A p.R526H | Missense Mutation (SNP) | VAF 110/314 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0.019); catalogued as rs144524810; called by muse, mutect2, varscan2
- FBXW8 | c.1357C>T p.R453C (on ENST00000309909; = p.R491C on NM_012174.1) | Missense Mutation (SNP) | VAF 88/202 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs569559960, COSV59296965; called by muse, mutect2
- FCHO2 | c.2423C>T p.A808V | Missense Mutation (SNP) | VAF 81/243 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.233); catalogued as rs750891864, COSV100530916; called by muse, mutect2, varscan2
- FGD5 | c.1151C>T p.A384V | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs374659688; called by muse, mutect2, varscan2
- FGD6 | c.3641C>T p.S1214L | Missense Mutation (SNP) | VAF 95/292 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as rs751711117; called by muse, mutect2, varscan2
- FN1 | c.2429C>T p.A810V | Missense Mutation (SNP) | VAF 136/450 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs568343071, COSV60556815, COSV60558955; called by mutect2, varscan2
- FOXD4L5 | c.1046G>A p.R349H | Missense Mutation (SNP) | VAF 36/217 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.277); catalogued as rs1182120702; called by mutect2, varscan2
- FOXN4 | c.407C>T p.P136L | Missense Mutation (SNP) | VAF 82/224 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs763259820; called by muse, mutect2, varscan2
- FRMPD1 | c.3511G>A p.E1171K | Missense Mutation (SNP) | VAF 141/375 reads (38%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.04); catalogued as rs551468496; called by muse, mutect2, varscan2
- FRY | c.5497G>A p.V1833I | Missense Mutation (SNP) | VAF 123/333 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.364); catalogued as rs746843324, COSV66569562; called by muse, mutect2, varscan2
- FSIP2 | c.102C>T p.G34= | Splice Region (SNP) | VAF 23/67 reads (34%) | catalogued as rs993154283, COSV58102360; called by muse, mutect2, varscan2
- FZD9 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 70/221 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs376108024, COSV60670996; called by muse, mutect2, varscan2
- G6PD | c.310C>T p.R104C | Missense Mutation (SNP) | VAF 154/436 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.026); catalogued as rs782372471, COSV63703068; called by muse, mutect2, varscan2
- GABPB2 | c.842C>A p.P281H | Missense Mutation (SNP) | VAF 67/172 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV64461657; called by muse, mutect2, varscan2
- GALNT13 | c.916G>T p.G306* | Nonsense Mutation (SNP) | VAF 91/229 reads (40%) | catalogued as COSV67220334; called by muse, mutect2, varscan2
- GALNT15 | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 72/212 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV60218044; called by muse, mutect2, varscan2
- GARRE1 | c.625G>A p.G209S | Missense Mutation (SNP) | VAF 141/436 reads (32%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0); catalogued as rs1329156111, COSV100209272; called by muse, mutect2, varscan2
- GAS2L1 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs774125414; called by muse, mutect2, varscan2
- GAS6 | c.1679C>T p.T560M | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.063); catalogued as rs779434253, COSV59849821; called by muse, mutect2
- GBP1 | c.1001A>G p.H334R | Missense Mutation (SNP) | VAF 169/525 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.304); catalogued as rs764674329; called by muse, mutect2, varscan2
- GFUS | c.391-8G>A | Splice Region (SNP) | VAF 47/145 reads (32%) | catalogued as rs375535808; called by muse, mutect2, varscan2
- GLG1 | c.2770C>T p.R924C | Missense Mutation (SNP) | VAF 117/308 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52672059, COSV99215366; called by muse, mutect2, varscan2
- GNL1 | c.571G>A p.V191I | Missense Mutation (SNP) | VAF 82/273 reads (30%) | SIFT tolerated (0.6); PolyPhen benign (0.02); catalogued as rs754395828, COSV100925386; called by muse, mutect2, varscan2
- GOLGA3 | c.946G>A p.D316N | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.999); catalogued as rs773984459; called by muse, mutect2, varscan2
- GOLGA6L7 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 162/397 reads (41%) | SIFT tolerated (0.44); PolyPhen benign (0.245); catalogued as rs779488791; called by muse, mutect2, varscan2
- GOLGA8R | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 30/484 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0.029); catalogued as rs1436675900; called by muse, mutect2
- GOLGA8S | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 88/412 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.086); catalogued as rs980797488; called by muse, mutect2, varscan2
- GPATCH8 | c.289C>T p.R97W | Missense Mutation (SNP) | VAF 168/486 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as rs1250210549, COSV59200349; called by muse, mutect2, varscan2
- GPBAR1 | c.881C>T p.A294V | Missense Mutation (SNP) | VAF 104/255 reads (41%) | SIFT tolerated (0.63); PolyPhen benign (0.033); catalogued as rs753677730; called by muse, mutect2, varscan2
- GPR17 | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 89/224 reads (40%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as rs376520675; called by muse, mutect2, varscan2
- GPR179 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs758334393; called by muse, mutect2
- GPR6 | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 16/383 reads (4%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.572); catalogued as rs1488665352, COSV51571468; called by muse, mutect2
- GPSM1 | c.824C>T p.T275M | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs782715651, COSV61305341; called by muse, mutect2, varscan2
- GRAMD1A | c.1663C>T p.R555W | Missense Mutation (SNP) | VAF 64/155 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs769137476; called by muse, mutect2, varscan2
- GRB14 | c.823C>T p.R275W | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs570762396, COSV55738001; called by muse, mutect2, varscan2
- GRIN2A | c.3925C>T p.R1309W | Missense Mutation (SNP) | VAF 185/456 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs145602289, COSV100409014; called by muse, mutect2, varscan2
- GRIN2D | c.3968G>A p.R1323H | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as rs747098261; called by muse, mutect2, varscan2
- GRM2 | c.1886C>T p.T629M | Missense Mutation (SNP) | VAF 102/326 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.219); catalogued as rs746682496; called by muse, mutect2, varscan2
- GSE1 | c.2549G>A p.S850N | Missense Mutation (SNP) | VAF 119/380 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1567754204, COSV53672523; called by muse, mutect2, varscan2
- GTF3C1 | c.1346G>A p.R449H | Missense Mutation (SNP) | VAF 89/275 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs746707529, COSV62242511; called by muse, mutect2, varscan2
- H1-7 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 173/452 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as rs1398378737; called by muse, mutect2, varscan2
- H2BC7 | c.128A>G p.Y43C | Missense Mutation (SNP) | VAF 163/414 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV61911790, COSV61912523; called by muse, mutect2, varscan2
- H3-4 | c.127C>T p.R43W | Missense Mutation (SNP) | VAF 52/326 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); catalogued as COSV64210511; called by muse, mutect2, varscan2
- HAPLN1 | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.17); catalogued as rs555462462, COSV57145600; called by muse, mutect2, varscan2
- HAUS3 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 125/341 reads (37%) | SIFT tolerated (0.53); PolyPhen benign (0.029); catalogued as rs760662072; called by muse, mutect2, varscan2
- HCFC1 | c.551T>C p.V184A | Missense Mutation (SNP) | VAF 83/244 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.598); catalogued as COSV60076514; called by muse, mutect2, varscan2
- HDGFL2 | c.677del p.K226Rfs*45 | Frame Shift Del (DEL) | VAF 65/217 reads (30%) | catalogued as rs1219916331, COSV56682191; called by mutect2, varscan2
- HERC2 | c.10372G>A p.E3458K | Missense Mutation (SNP) | VAF 80/213 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0.236); catalogued as rs370685397; called by muse, mutect2, varscan2
- HGFAC | c.1537C>T p.R513C | Missense Mutation (SNP) | VAF 94/262 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs565681719; called by muse, mutect2
- HLA-G | c.763G>A p.V255M | Missense Mutation (SNP) | VAF 204/521 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.382); catalogued as rs1216496794, COSV64405247, COSV64405301; called by muse, mutect2, varscan2
- HMCN2 | c.11665G>A p.A3889T | Missense Mutation (SNP) | VAF 50/160 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs979077653, COSV99478513; called by muse, mutect2, varscan2
- HOXD4 | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 86/213 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as rs767411850; called by muse, mutect2, varscan2
- HSD17B4 | c.1702C>T p.R568C (on ENST00000414835 / NM_001199291.3; = p.R543C on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 152/427 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as rs775326908; called by muse, mutect2, varscan2
- HYDIN | c.1804C>T p.R602C | Missense Mutation (SNP) | VAF 102/263 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs372720976, COSV55481350; called by muse, mutect2, varscan2
- ICAM3 | c.358G>A p.V120M | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs1275112086; called by muse, mutect2, varscan2
- IFNGR1 | c.34C>T p.Q12* | Nonsense Mutation (SNP) | VAF 188/526 reads (36%) | catalogued as COSV100880472; called by muse, mutect2, varscan2
- IFT81 | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 47/176 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.03); catalogued as rs765241061, COSV54365872; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGLON5 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 47/118 reads (40%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.746); catalogued as rs779810845, COSV54536211, COSV54536292; called by muse, mutect2, varscan2
- IKBIP | c.931G>A p.D311N | Missense Mutation (SNP) | VAF 68/196 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs554996429; called by muse, mutect2, varscan2
- IL1RL1 | c.1315C>T p.R439* | Nonsense Mutation (SNP) | VAF 54/148 reads (36%) | catalogued as rs764765442; called by muse, mutect2
- INPP5D | c.1301C>T p.T434M (on ENST00000445964 / NM_001017915.3; = p.T433M on NM_005541.5) | Missense Mutation (SNP) | VAF 159/453 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1455642398, COSV64039767; called by muse, varscan2
- INPP5F | c.2743G>A p.V915I | Missense Mutation (SNP) | VAF 94/294 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs149605875; called by muse, mutect2, varscan2
- INPPL1 | c.1497G>A p.P499= | Splice Region (SNP) | VAF 66/140 reads (47%) | catalogued as rs763467176; called by muse, mutect2, varscan2
- INPPL1 | c.2122G>A p.G708S | Missense Mutation (SNP) | VAF 116/280 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as rs1254768648; called by muse, mutect2, varscan2
- IQCN | c.1271C>T p.T424M | Missense Mutation (SNP) | VAF 74/214 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs141411066; called by muse, mutect2, varscan2
- IRF5 | c.248C>T p.P83L | Missense Mutation (SNP) | VAF 78/283 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774453718; called by muse, mutect2, varscan2
- IRX6 | c.944G>A p.R315H | Missense Mutation (SNP) | VAF 131/342 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV51858898; called by muse, mutect2, varscan2
- ITGA8 | c.1667C>T p.T556M | Missense Mutation (SNP) | VAF 89/264 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs147309422; called by muse, mutect2, varscan2
- ITGAL | c.353C>T p.T118M | Missense Mutation (SNP) | VAF 80/224 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as rs780099281; called by muse, mutect2, varscan2
- ITGB7 | c.2206G>A p.V736M | Missense Mutation (SNP) | VAF 86/248 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs926770238, COSV99914213; called by muse, mutect2, varscan2
- ITGBL1 | c.1097G>A p.R366H | Missense Mutation (SNP) | VAF 91/288 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as rs765315193, COSV66007930, COSV66011288; called by muse, mutect2, varscan2
- ITPK1 | c.1108G>A p.A370T | Missense Mutation (SNP) | VAF 121/328 reads (37%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as rs761329471, COSV50893921; called by muse, mutect2, varscan2
- ITPK1 | c.277G>A p.V93I | Missense Mutation (SNP) | VAF 71/180 reads (39%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs768335687, COSV50896261; called by muse, mutect2, varscan2
- JMJD1C | c.3701C>T p.P1234L | Missense Mutation (SNP) | VAF 81/289 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1237216547, COSV100550432, COSV59517692; called by muse, mutect2, varscan2
- JPH1 | c.427G>A p.V143M | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.211); catalogued as rs1395214888; called by muse, mutect2, varscan2
- JPH3 | c.379G>A p.G127R | Missense Mutation (SNP) | VAF 48/161 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs751969456; called by muse, mutect2, varscan2
- KANK1 | c.29G>A p.S10N | Missense Mutation (SNP) | VAF 66/194 reads (34%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.01); catalogued as rs781523271; called by muse, mutect2, varscan2
- KAT6A | c.5600C>T p.A1867V | Missense Mutation (SNP) | VAF 58/159 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.758); catalogued as rs145754397; called by muse, mutect2, varscan2
- KAT6B | c.2062G>A p.V688I | Missense Mutation (SNP) | VAF 180/497 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as rs550985531, COSV99767169; called by muse, mutect2, varscan2
- KBTBD13 | c.1028G>A p.G343D | Missense Mutation (SNP) | VAF 188/558 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs1437457186; called by muse, mutect2, varscan2
- KCNA10 | c.1117C>T p.R373W | Missense Mutation (SNP) | VAF 195/559 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs755353258, COSV100871396; called by muse, mutect2, varscan2
- KCNA6 | c.1180G>A p.V394I | Missense Mutation (SNP) | VAF 95/277 reads (34%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.514); catalogued as rs1285186513; called by muse, mutect2, varscan2
- KCNE5 | c.67C>T p.R23W | Missense Mutation (SNP) | VAF 75/210 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.534); catalogued as rs369739947, COSV64508700; called by muse, mutect2, varscan2
- KCNJ10 | c.689G>A p.R230Q | Missense Mutation (SNP) | VAF 110/332 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.034); catalogued as rs200807361; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNJ15 | c.676G>T p.E226* | Nonsense Mutation (SNP) | VAF 26/326 reads (8%) | catalogued as COSV100154451; called by muse, mutect2
- KCTD15 | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 50/158 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.681); catalogued as rs1214196246; called by muse, mutect2
- KCTD2 | c.514C>T p.R172W | Missense Mutation (SNP) | VAF 122/336 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100483310; called by muse, mutect2, varscan2
- KDM6B | c.1537del p.R513Afs*69 | Frame Shift Del (DEL) | VAF 87/245 reads (36%) | catalogued as rs747555402; called by mutect2, pindel, varscan2
- KHSRP | c.785G>A p.R262H | Missense Mutation (SNP) | VAF 52/152 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1013966576; called by muse, mutect2, varscan2
- KIAA0825 | c.431C>T p.T144M | Missense Mutation (SNP) | VAF 95/315 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as rs754807072, COSV56947332; called by muse, mutect2, varscan2
- KIAA1522 | c.2377G>A p.V793M (on ENST00000373480 / NM_001198972.2; = p.V852M on NM_020888.3) | Missense Mutation (SNP) | VAF 49/132 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as COSV99614518; called by muse, mutect2, varscan2
- KIF26A | c.1592G>A p.R531Q | Missense Mutation (SNP) | VAF 101/271 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.06); catalogued as rs1025697280, COSV100180975; called by muse, mutect2, varscan2
- KIF26A | c.1679C>T p.A560V | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.278); catalogued as rs371178408; called by muse, mutect2, varscan2
- KMT2C | c.1481T>C p.L494P | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as rs771266223; called by muse, mutect2, varscan2
- KMT2D | c.1711C>T p.R571C | Missense Mutation (SNP) | VAF 91/246 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs1263886473, COSV56427221; called by muse, mutect2, varscan2
- KMT5C | c.106G>A p.V36I | Missense Mutation (SNP) | VAF 90/229 reads (39%) | SIFT tolerated (0.42); PolyPhen benign (0.054); catalogued as rs774927761, COSV55318841, COSV55320455; called by muse, mutect2, varscan2
- KRT5 | c.1754G>A p.R585Q | Missense Mutation (SNP) | VAF 53/146 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.885); catalogued as rs776384768; called by muse, mutect2, varscan2
- KRT79 | c.614C>T p.T205M | Missense Mutation (SNP) | VAF 119/345 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as rs149430221; called by muse, mutect2, varscan2
- LAMA5 | c.6830C>T p.T2277M | Missense Mutation (SNP) | VAF 52/174 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as rs571296023; called by muse, mutect2, varscan2
- LCT | c.1876T>C p.F626L | Missense Mutation (SNP) | VAF 68/208 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV99929350; called by muse, mutect2, varscan2
- LDHB | c.714-4del | Splice Region (DEL) | VAF 114/341 reads (33%) | catalogued as rs34439838; called by mutect2, pindel, varscan2
- LGI4 | c.1016C>T p.A339V | Missense Mutation (SNP) | VAF 102/302 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as rs963097948; called by muse, mutect2, varscan2
- LILRB1 | c.1283C>T p.A428V (on ENST00000427581; = p.A392V on NM_006669.6) | Missense Mutation (SNP) | VAF 115/351 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.041); catalogued as rs377750177, COSV61115805; called by muse, mutect2, varscan2
- LILRB2 | c.1687G>A p.A563T | Missense Mutation (SNP) | VAF 141/457 reads (31%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs140594886; called by muse, mutect2, varscan2
- LIPG | c.943C>T p.R315C | Missense Mutation (SNP) | VAF 245/743 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1477413888, COSV54295671; called by muse, mutect2, varscan2
- LMAN2 | c.661C>T p.R221W | Missense Mutation (SNP) | VAF 96/253 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.83); catalogued as rs139732914; called by muse, mutect2, varscan2
- LMF2 | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 56/180 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373075701; called by muse, mutect2, varscan2
- LMLN2 | c.571C>T p.R191* | Nonsense Mutation (SNP) | VAF 63/152 reads (41%) | catalogued as rs764530848; called by muse, mutect2, varscan2
- LONP1 | c.11G>A p.S4N | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.014); catalogued as rs747472062; called by muse, mutect2, varscan2
- LRP1 | c.9797C>T p.T3266M | Missense Mutation (SNP) | VAF 97/288 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.475); catalogued as rs569713960; called by muse, mutect2, varscan2
- LRP3 | c.157C>T p.R53W | Missense Mutation (SNP) | VAF 43/151 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs753467105, COSV53508996; called by muse, mutect2, varscan2
- LRRC41 | c.1688G>A p.R563Q | Missense Mutation (SNP) | VAF 153/412 reads (37%) | SIFT tolerated (0.59); PolyPhen benign (0.112); catalogued as rs1482893246; called by muse, mutect2, varscan2
- LRRC49 | c.976C>T p.R326W | Missense Mutation (SNP) | VAF 64/217 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1457514278; called by muse, mutect2, varscan2
- LRRC7 | c.247G>A p.E83K (on ENST00000651989 / NM_001370785.2; = p.E50K on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 109/353 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV50447554, COSV99224979; called by muse, mutect2, varscan2
- LRRC8A | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 81/222 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs201084502, COSV99396151; called by muse, mutect2, varscan2
- LRRTM1 | c.959G>A p.R320H | Missense Mutation (SNP) | VAF 85/272 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.869); catalogued as COSV54440125; called by muse, mutect2, varscan2
- LTBP2 | c.4799G>A p.R1600H | Missense Mutation (SNP) | VAF 220/508 reads (43%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as rs375314974; called by muse, mutect2, varscan2
- LTBP4 | c.3781C>T p.R1261* (on ENST00000308370 / NM_001042544.1; = p.R1224* on NM_003573.2) | Nonsense Mutation (SNP) | VAF 52/130 reads (40%) | catalogued as COSV52592897; called by muse, mutect2, varscan2
- LTF | c.19G>A p.V7I | Missense Mutation (SNP) | VAF 91/288 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs956266128; called by muse, mutect2, varscan2
- LZTS1 | c.979G>A p.A327T | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs141696144; called by muse, mutect2, varscan2
- LZTS1 | c.107G>A p.R36Q | Missense Mutation (SNP) | VAF 112/337 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.662); catalogued as rs1416863808; called by muse, mutect2, varscan2
- MACF1 | c.1711C>T p.R571W | Missense Mutation (SNP) | VAF 148/472 reads (31%) | catalogued as rs771371955; called by muse, mutect2, varscan2
- MAGEB3 | c.56G>A p.R19Q | Missense Mutation (SNP) | VAF 65/176 reads (37%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as rs150405296, COSV100854728, COSV64396830; called by muse, mutect2, varscan2
- MANEAL | c.1102C>T p.R368W (on ENST00000373045 / NM_001113482.1; = p.R146W on NM_152496.2) | Missense Mutation (SNP) | VAF 120/352 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766770261, COSV100203947; called by muse, mutect2, varscan2
- MAP11 | c.884G>A p.R295H | Missense Mutation (SNP) | VAF 71/243 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs2293477; called by muse, mutect2, varscan2
- MAP1B | c.1673G>A p.R558H | Missense Mutation (SNP) | VAF 135/341 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs756043501, COSV57107037; called by muse, mutect2, varscan2
- MAP3K13 | c.1406G>A p.R469H | Missense Mutation (SNP) | VAF 60/145 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs540323344, COSV53993325; called by muse, mutect2, varscan2
- MAP3K15 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 74/192 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as rs952671859; called by muse, mutect2, varscan2
- MAP3K6 | c.1747C>T p.R583C | Missense Mutation (SNP) | VAF 97/255 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1259680267, COSV100709288; called by muse, mutect2, varscan2
- MARK1 | c.1873G>A p.V625I | Missense Mutation (SNP) | VAF 160/469 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs369987878, COSV99081355; called by muse, mutect2, varscan2
- MASP2 | c.1874G>A p.G625D | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs1192739905; called by muse, mutect2, varscan2
- MAST1 | c.322G>A p.V108I | Missense Mutation (SNP) | VAF 55/147 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.27); catalogued as rs138461183; called by muse, mutect2, varscan2
- MBD3 | c.712C>T p.R238W | Missense Mutation (SNP) | VAF 171/437 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1306115519; called by muse, mutect2, varscan2
- MCF2L2 | c.2495C>T p.P832L | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.927); catalogued as rs893129303; called by muse, mutect2, varscan2
- MCM6 | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 124/369 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0.389); catalogued as rs777694769, COSV51466836; called by muse, mutect2, varscan2
- MDN1 | c.8411G>A p.R2804Q | Missense Mutation (SNP) | VAF 81/195 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.248); catalogued as rs770689428; called by muse, mutect2, varscan2
- MEAK7 | c.1331G>A p.R444H | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as rs200383674, COSV100640420, COSV100640432; called by muse, mutect2, varscan2
- MED13L | c.5615G>A p.R1872H | Missense Mutation (SNP) | VAF 210/570 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs28940310, CM033936; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MED25 | c.1968G>A p.P656= | Splice Region (SNP) | VAF 97/277 reads (35%) | catalogued as rs370950491; called by muse, mutect2, varscan2
- MED7 | c.196C>T p.R66W | Missense Mutation (SNP) | VAF 67/179 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs1211935997, COSV53850367; called by muse, mutect2, varscan2
- MEGF9 | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 104/364 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.027); catalogued as rs773125417; called by muse, mutect2, varscan2
- METTL24 | c.325C>T p.R109W | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200158177; called by muse, mutect2, varscan2
- METTL9 | c.919G>A p.V307I | Missense Mutation (SNP) | VAF 76/225 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.141); catalogued as rs778358052, COSV99193658; called by muse, mutect2, varscan2
- MFGE8 | c.428C>T p.T143M | Missense Mutation (SNP) | VAF 122/321 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs772280903, COSV51556018; called by muse, mutect2, varscan2
- MFSD14B | c.917C>T p.T306M | Missense Mutation (SNP) | VAF 42/148 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs745326058, COSV64700669; called by muse, varscan2
- MGA | c.4591C>T p.R1531* | Nonsense Mutation (SNP) | VAF 46/119 reads (39%) | catalogued as COSV99580027; called by muse, mutect2, varscan2
- MGAM2 | c.2054C>T p.T685M | Missense Mutation (SNP) | VAF 70/198 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs535782000; called by muse, mutect2, varscan2
- MIB2 | c.1811C>T p.A604V | Missense Mutation (SNP) | VAF 99/248 reads (40%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.926); catalogued as rs376634991; called by muse, varscan2
- MIB2 | c.2285G>A p.R762H | Missense Mutation (SNP) | VAF 73/212 reads (34%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.591); catalogued as rs1029544868; called by muse, mutect2, varscan2
- MIB2 | c.2795C>T p.T932M | Missense Mutation (SNP) | VAF 70/212 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1196456089; called by muse, mutect2, varscan2
- MIGA2 | c.1246C>T p.R416W | Missense Mutation (SNP) | VAF 69/230 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs1163689629; called by muse, mutect2, varscan2
- MON2 | c.3973G>A p.E1325K | Missense Mutation (SNP) | VAF 55/167 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.199); catalogued as rs199973736, COSV54803850, COSV54814318; called by muse, mutect2, varscan2
- MPPE1 | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs372251919; called by muse, mutect2, varscan2
- MRGPRE | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs775828603; called by muse, mutect2, varscan2
- MRPS18C | c.150+16del | Splice Region (DEL) | VAF 56/180 reads (31%) | catalogued as rs199634680; called by mutect2, varscan2
- MRPS30 | c.724C>T p.R242* | Nonsense Mutation (SNP) | VAF 75/150 reads (50%) | catalogued as rs201364888, COSV50181558; called by muse, mutect2, varscan2
- MRPS31 | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 106/297 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs377071174; called by muse, mutect2, varscan2
- MRPS35 | c.945del p.V316* | Frame Shift Del (DEL) | VAF 35/106 reads (33%) | catalogued as COSV50011264; called by mutect2, pindel, varscan2
- MSC | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs745467298, COSV57696589; called by muse, mutect2, varscan2
- MSH2 | c.2272G>A p.D758N | Missense Mutation (SNP) | VAF 100/267 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs876658254, COSV51879119; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MTCL1 | c.1688G>A p.R563Q (on ENST00000306329 / NM_001378206.1; = p.R203Q on NM_015210.4) | Missense Mutation (SNP) | VAF 59/163 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747425095, COSV100095468; called by muse, mutect2, varscan2
- MTMR11 | c.1226G>A p.R409Q (on ENST00000439741 / NM_001145862.2; = p.R337Q on NM_181873.3) | Missense Mutation (SNP) | VAF 88/280 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.185); catalogued as rs1553767600, COSV54966559; called by muse, mutect2, varscan2
- MTREX | c.848C>T p.S283L | Missense Mutation (SNP) | VAF 74/249 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57925893; called by muse, mutect2, varscan2
- MUC15 | c.956G>A p.R319H | Missense Mutation (SNP) | VAF 98/255 reads (38%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as rs775565810; called by muse, mutect2, varscan2
- MUC21 | c.1693G>A p.G565R | Missense Mutation (SNP) | VAF 60/142 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as rs747007598, COSV66220373; called by muse, mutect2
- MUC4 | c.15701C>T p.S5234L (on ENST00000463781 / NM_018406.7; = p.S998L on NM_004532.6) | Missense Mutation (SNP) | VAF 162/424 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.893); catalogued as rs1011941967; called by muse, mutect2, varscan2
- MUC4 | c.2591C>A p.A864E | Missense Mutation (SNP) | VAF 84/284 reads (30%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.598); catalogued as rs372862585; called by muse, mutect2, varscan2
- MUC6 | c.1708G>A p.A570T | Missense Mutation (SNP) | VAF 72/176 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as rs757784693; called by muse, mutect2, varscan2
- MYBPC3 | c.3362G>A p.R1121H | Missense Mutation (SNP) | VAF 72/170 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.028); catalogued as rs397516018; ClinVar: uncertain significance / likely benign / benign; called by muse, mutect2, varscan2
- MYCT1 | c.4C>T p.R2* | Nonsense Mutation (SNP) | VAF 61/168 reads (36%) | catalogued as rs1320878743; called by muse, mutect2, varscan2
- MYH11 | c.2195C>T p.A732V | Missense Mutation (SNP) | VAF 250/781 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.414); catalogued as rs764831521, CM158366, COSV100259661; called by muse, mutect2, varscan2
- MYH13 | c.1064C>T p.T355M | Missense Mutation (SNP) | VAF 59/168 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV52841720; called by muse, mutect2, varscan2
- MYH7B | c.1196C>T p.A399V | Missense Mutation (SNP) | VAF 73/242 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as rs762281928; called by muse, mutect2, varscan2
- MYO10 | c.5208G>T p.E1736D | Missense Mutation (SNP) | VAF 102/263 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.061); catalogued as COSV57018552; called by muse, mutect2, varscan2
- MYO15A | c.9989C>T p.P3330L | Missense Mutation (SNP) | VAF 157/435 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.029); catalogued as rs773842831; called by muse, mutect2, varscan2
- MYO5A | c.4688G>A p.R1563Q | Missense Mutation (SNP) | VAF 184/532 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.773); catalogued as rs772825290; called by muse, mutect2, varscan2
- MYRF | c.257G>A p.R86H (on ENST00000278836 / NM_001127392.3; = p.R77H on NM_013279.4) | Missense Mutation (SNP) | VAF 42/134 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.572); catalogued as rs890374644, COSV53888088; called by muse, mutect2, varscan2
- MYT1 | c.3223C>T p.R1075C | Missense Mutation (SNP) | VAF 61/164 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs778035195, COSV60511987; called by muse, mutect2, varscan2
- NACAD | c.524C>T p.T175M | Missense Mutation (SNP) | VAF 44/125 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1280729084; called by muse, mutect2, varscan2
- NAXD | c.137C>T p.S46L | Missense Mutation (SNP) | VAF 75/187 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs1378945854, COSV59393616; called by muse, mutect2, varscan2
- NCAPD2 | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 154/416 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as rs757733418, COSV100217159; called by muse, mutect2, varscan2
- NCBP1 | c.2341G>A p.V781M | Missense Mutation (SNP) | VAF 75/255 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs377264051; called by muse, mutect2, varscan2
- NCBP2L | c.232G>T p.A78S | Missense Mutation (SNP) | VAF 96/274 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as rs748534965; called by muse, mutect2, varscan2
- NCOA1 | c.1555G>A p.V519I | Missense Mutation (SNP) | VAF 110/330 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs144856306; called by muse, mutect2, varscan2
- NDUFS7 | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 125/344 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs757627492, COSV99282554; called by muse, mutect2, varscan2
- NFASC | c.905G>A p.R302H (on ENST00000339876 / NM_001378329.1; = p.R313H on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 69/233 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs766397794, COSV100362403; called by muse, mutect2, varscan2
- NFASC | c.1339C>T p.R447W (on ENST00000339876 / NM_001378329.1; = p.R458W on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/219 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as rs774424825; called by muse, mutect2, varscan2
- NFXL1 | c.1370G>A p.R457Q | Missense Mutation (SNP) | VAF 69/183 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as rs1457122371; called by muse, mutect2, varscan2
- NGFR | c.1186G>A p.A396T | Missense Mutation (SNP) | VAF 82/220 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs753281503; called by muse, mutect2, varscan2
- NHLRC1 | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 81/239 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs1292042098; called by muse, mutect2, varscan2
- NID1 | c.1219G>A p.A407T | Missense Mutation (SNP) | VAF 64/206 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs765670423, COSV51618015; called by muse, mutect2, varscan2
- NIFK | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 96/303 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs185431138, COSV53534192, COSV99590654; called by muse, mutect2, varscan2
- NINL | c.2312G>A p.R771H | Missense Mutation (SNP) | VAF 96/311 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs770180886, COSV99625830; called by muse, mutect2, varscan2
- NIPAL2 | c.295G>A p.V99M | Missense Mutation (SNP) | VAF 85/241 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as rs1310752064, COSV57840160; called by muse, mutect2, varscan2
- NIT2 | c.778G>A p.V260I | Missense Mutation (SNP) | VAF 83/269 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs141525680; called by muse, mutect2, varscan2
- NKAIN1 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 65/197 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.448); catalogued as COSV99744797; called by muse, mutect2, varscan2
- NLGN1 | c.1448C>T p.T483M | Missense Mutation (SNP) | VAF 121/401 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV64344149; called by muse, mutect2, varscan2
- NLRP5 | c.1490C>T p.T497M | Missense Mutation (SNP) | VAF 126/408 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs779881731, COSV66761858; called by muse, varscan2
- NLRP9 | c.791dup p.M265Dfs*36 | Frame Shift Ins (INS) | VAF 63/191 reads (33%) | catalogued as rs745704129; called by mutect2, varscan2
- NODAL | c.418A>G p.T140A | Missense Mutation (SNP) | VAF 234/706 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs1176353462; called by muse, mutect2, varscan2
- NOP53 | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 87/249 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as rs752084705; called by muse, mutect2, varscan2
- NOS2 | c.1450G>A p.V484I | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as rs199558669; called by muse, mutect2, varscan2
- NPEPL1 | c.755C>T p.T252M | Missense Mutation (SNP) | VAF 68/179 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs777965170, COSV61938761; called by muse, mutect2, varscan2
- NPHP4 | c.3071G>T p.R1024M | Missense Mutation (SNP) | VAF 95/270 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100977158; called by muse, mutect2, varscan2
- NR1H2 | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 76/197 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as rs376476625, COSV53802782; called by muse, mutect2, varscan2
- NRAP | c.3946C>T p.R1316* (on ENST00000359988 / NM_001322945.2; = p.R1281* on NM_006175.4) | Nonsense Mutation (SNP) | VAF 69/157 reads (44%) | catalogued as rs760475597, COSV63491498; called by muse, mutect2, varscan2
- NRCAM | c.1243G>A p.D415N (on ENST00000379028 / NM_001371124.1; = p.D409N on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.273); catalogued as rs769699652; called by muse, mutect2, varscan2
- NTM | c.850A>G p.N284D | Missense Mutation (SNP) | VAF 44/153 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66195598; called by muse, mutect2, varscan2
- NUBPL | c.688G>A p.V230M | Missense Mutation (SNP) | VAF 155/421 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1479309023; called by muse, mutect2, varscan2
- NXPH3 | c.212C>T p.P71L | Missense Mutation (SNP) | VAF 57/167 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.166); catalogued as rs571014368, COSV60872052; called by muse, mutect2, varscan2
- OBI1 | c.1694A>G p.D565G | Missense Mutation (SNP) | VAF 121/329 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.398); catalogued as rs749517299; called by muse, mutect2, varscan2
- OBP2B | c.31G>A p.G11S | Missense Mutation (SNP) | VAF 80/348 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0.006); catalogued as rs782448613; called by muse, mutect2, varscan2
- OBSCN | c.3308C>T p.T1103M | Missense Mutation (SNP) | VAF 113/362 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.206); catalogued as rs550229754, COSV52778247; called by muse, mutect2, varscan2
- OBSCN | c.4973C>T p.T1658M | Missense Mutation (SNP) | VAF 174/479 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.487); catalogued as rs374036309; called by muse, mutect2, varscan2
- OBSCN | c.5557C>T p.R1853C | Missense Mutation (SNP) | VAF 135/395 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs376658835; called by muse, mutect2, varscan2
- OBSCN | c.19052C>T p.T6351M | Missense Mutation (SNP) | VAF 71/221 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs200636677; called by muse, mutect2, varscan2
- ODAM | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs758616960; called by muse, mutect2, varscan2
- OLFML2A | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 122/327 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs765128055, COSV59161557; called by muse, mutect2, varscan2
- OPA1 | c.2818C>T p.R940C (on ENST00000361510 / NM_130837.3; = p.R885C on NM_015560.3) | Missense Mutation (SNP) | VAF 124/349 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs927450242; called by mutect2, varscan2
- OR10C1 | c.766G>A p.A256T (on ENST00000622521; = p.A254T on NM_013941.3) | Missense Mutation (SNP) | VAF 135/337 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as rs374582900, COSV65824422; called by muse, mutect2, varscan2
- OR2AP1 | c.184C>T p.R62W | Missense Mutation (SNP) | VAF 106/271 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); catalogued as rs779875070, COSV58725408; called by muse, mutect2, varscan2
- OR2F1 | c.178T>C p.Y60H | Missense Mutation (SNP) | VAF 63/182 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1276097754, COSV101231291; called by muse, mutect2, varscan2
- OR4K2 | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 72/411 reads (18%) | SIFT tolerated (0.56); PolyPhen probably damaging (1); catalogued as rs141210026, COSV100063939; called by muse, mutect2, varscan2
- OR52N4 | c.863C>T p.P288L | Missense Mutation (SNP) | VAF 159/456 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as COSV100421682; called by muse, mutect2, varscan2
- OR5D18 | c.528T>A p.N176K | Missense Mutation (SNP) | VAF 151/413 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.588); catalogued as rs768143169, COSV100450837; called by muse, mutect2, varscan2
- OSBPL5 | c.1228G>A p.A410T | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as rs780486148; called by muse, mutect2, varscan2
- OSBPL9 | c.557C>T p.A186V | Missense Mutation (SNP) | VAF 75/241 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1193625406, COSV61875475; called by muse, mutect2, varscan2
- OTOG | c.6747C>T p.C2249= | Splice Region (SNP) | VAF 31/102 reads (30%) | catalogued as rs562749083; called by muse, mutect2, varscan2
- OTUD6B | c.783del p.K261Nfs*3 | Frame Shift Del (DEL) | VAF 64/224 reads (29%) | catalogued as rs762934606; called by pindel, varscan2
- OVGP1 | c.1150C>T p.R384W | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs895639584, COSV63858046; called by muse, mutect2, varscan2
- P2RX4 | c.473C>T p.T158M | Missense Mutation (SNP) | VAF 98/286 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766636794; called by muse, mutect2, varscan2
- PABPC1L | c.775C>T p.R259W | Missense Mutation (SNP) | VAF 51/176 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); catalogued as rs745399542, COSV53839423; called by muse, mutect2, varscan2
- PALD1 | c.2516G>A p.R839Q | Missense Mutation (SNP) | VAF 69/196 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781675921, COSV99698633; called by muse, mutect2, varscan2
- PASK | c.1960C>T p.R654* | Nonsense Mutation (SNP) | VAF 86/245 reads (35%) | catalogued as rs200120797; called by muse, mutect2, varscan2
- PAX8 | c.857G>A p.G286E | Missense Mutation (SNP) | VAF 96/268 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as rs1396991771; called by muse, mutect2, varscan2
- PBX1 | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 89/266 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.625); catalogued as rs1458267934, COSV61538968; called by muse, mutect2, varscan2
- PCDH9 | c.3149G>A p.R1050H (on ENST00000377865 / NM_203487.3; = p.R1016H on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 80/215 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as rs754586265, COSV60540393; called by muse, mutect2, varscan2
- PCDHA10 | c.286G>A p.G96R | Missense Mutation (SNP) | VAF 189/554 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.298); catalogued as COSV56503315; called by muse, mutect2, varscan2
- PCDHA5 | c.1459G>A p.A487T | Missense Mutation (SNP) | VAF 272/768 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV65352453; called by muse, varscan2
- PCDHA8 | c.1760C>T p.A587V | Missense Mutation (SNP) | VAF 210/583 reads (36%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as rs564409198, COSV100969336; called by muse, mutect2, varscan2
- PCDHGA6 | c.65C>T p.T22M | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.018); catalogued as COSV53894469; called by muse, mutect2, varscan2
- PCDHGC4 | c.685C>T p.R229W | Missense Mutation (SNP) | VAF 103/297 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.657); catalogued as rs1431906047; called by muse, mutect2, varscan2
- PCNX3 | c.3136C>T p.R1046C | Missense Mutation (SNP) | VAF 63/176 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as rs1272552644, COSV63141260; called by muse, mutect2, varscan2
- PDCD10 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 108/354 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.305); catalogued as rs771126809; called by muse, mutect2, varscan2
- PDE6B | c.1861G>A p.G621S | Missense Mutation (SNP) | VAF 124/349 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.377); catalogued as rs757161177, COSV55327656; called by muse, mutect2, varscan2
- PER2 | c.1420G>A p.V474I | Missense Mutation (SNP) | VAF 53/164 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs372278249; called by muse, mutect2, varscan2
- PFN3 | c.313C>T p.R105C | Missense Mutation (SNP) | VAF 115/329 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as rs559554775, COSV99499825; called by muse, mutect2, varscan2
- PGAP4 | c.398G>A p.G133D | Missense Mutation (SNP) | VAF 79/215 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV66387782; called by muse, mutect2, varscan2
- PHLDB1 | c.1264C>T p.R422C | Missense Mutation (SNP) | VAF 169/460 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs201776369; called by muse, mutect2, varscan2
- PHLDB1 | c.3503C>T p.S1168L | Missense Mutation (SNP) | VAF 100/311 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as rs781803750, COSV61881173; called by muse, mutect2, varscan2
- PICALM | c.376C>T p.R126W | Missense Mutation (SNP) | VAF 42/162 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs1160579539, COSV62668962; called by muse, mutect2, varscan2
- PIDD1 | c.1948C>T p.R650W | Missense Mutation (SNP) | VAF 85/254 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs149217765; called by muse, mutect2, varscan2
- PIK3AP1 | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 48/145 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs770855063; called by muse, mutect2, varscan2
- PIK3C2A | c.4919G>A p.R1640Q | Missense Mutation (SNP) | VAF 60/128 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370271506, COSV56400159; called by muse, mutect2, varscan2
- PIK3R1 | c.1924C>T p.R642* (on ENST00000521381 / NM_181523.3; = p.R372* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 64/201 reads (32%) | catalogued as rs1419325070, COSV57123056; called by muse, mutect2, varscan2
- PIK3R1 | c.2047G>A p.E683K (on ENST00000521381 / NM_181523.3; = p.E413K on NM_181504.4) | Missense Mutation (SNP) | VAF 95/226 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57122880, COSV57131493; called by muse, mutect2, varscan2
- PIKFYVE | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 176/514 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as rs758117456; called by muse, mutect2, varscan2
- PITPNC1 | c.715C>T p.R239* | Nonsense Mutation (SNP) | VAF 45/160 reads (28%) | catalogued as COSV55458305; called by muse, mutect2, varscan2
- PKD1L2 | n.1371C>T | Splice Region (SNP) | VAF 81/211 reads (38%) | catalogued as rs200846553; called by muse, mutect2
- PLCD3 | c.1223G>A p.R408Q | Missense Mutation (SNP) | VAF 74/229 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.95); catalogued as rs749683999; called by muse, mutect2, varscan2
- PLCXD2 | c.769C>T p.R257W | Missense Mutation (SNP) | VAF 108/318 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.153); catalogued as rs527314934, COSV67340739; called by muse, varscan2
- PLEC | c.3286G>A p.G1096S (on ENST00000322810 / NM_201380.4; = p.G986S on NM_000445.5) | Missense Mutation (SNP) | VAF 151/427 reads (35%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs201071539; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEK | c.548C>T p.S183L | Missense Mutation (SNP) | VAF 90/242 reads (37%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.498); catalogued as rs148824923; called by muse, mutect2, varscan2
- PLEKHG5 | c.1691C>T p.A564V (on ENST00000400915 / NM_001042663.3; = p.A527V on NM_020631.6) | Missense Mutation (SNP) | VAF 133/365 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.183); catalogued as rs768978784, COSV100556433; called by muse, mutect2, varscan2
- PLEKHG6 | c.1895G>A p.R632H | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.994); catalogued as rs754002278, COSV50598267; called by muse, mutect2, varscan2
- PLIN3 | c.572C>T p.T191M | Missense Mutation (SNP) | VAF 134/298 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); catalogued as rs369269065; called by muse, mutect2, varscan2
- PLP1 | c.799G>A p.V267I | Missense Mutation (SNP) | VAF 238/573 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs137966879, COSV58275706; called by muse, mutect2, varscan2
- PLXNA3 | c.49del p.A17Pfs*12 | Frame Shift Del (DEL) | VAF 56/146 reads (38%) | catalogued as rs782247826; called by mutect2, varscan2
- PM20D1 | c.1238G>A p.R413H | Missense Mutation (SNP) | VAF 80/239 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as rs200541177; called by muse, mutect2, varscan2
- PNPLA7 | c.3890G>A p.R1297Q | Missense Mutation (SNP) | VAF 60/159 reads (38%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as rs776279157; called by muse, mutect2, varscan2
- POLR1B | c.2404C>T p.R802C | Missense Mutation (SNP) | VAF 146/408 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs200576643, COSV54504201; called by muse, mutect2, varscan2
- POLR3A | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 196/604 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs771607996, COSV100965620; called by muse, mutect2, varscan2
- POMGNT2 | c.1475C>T p.A492V | Missense Mutation (SNP) | VAF 103/298 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.054); catalogued as rs769359700, COSV60953039; called by muse, mutect2, varscan2
- POTEF | c.2395G>A p.E799K | Missense Mutation (SNP) | VAF 287/743 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.948); catalogued as rs754169172, COSV62541227; called by muse, mutect2, varscan2
- PPME1 | c.340A>G p.S114G | Missense Mutation (SNP) | VAF 86/271 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1050244648; called by muse, mutect2, varscan2
- PPP1R3F | c.404T>C p.M135T | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.546); catalogued as rs782410643; called by muse, mutect2, varscan2
- PPP6R1 | c.574G>A p.V192I | Missense Mutation (SNP) | VAF 100/288 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs764069727, COSV101336988; called by muse, mutect2, varscan2
- PRB2 | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 56/204 reads (27%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.197); catalogued as rs745548592; called by muse, mutect2, varscan2
- PRC1 | c.1259C>T p.A420V | Missense Mutation (SNP) | VAF 94/281 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.046); catalogued as rs139840373; called by muse, mutect2, varscan2
- PRDM1 | c.1136C>T p.A379V | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs368185616; called by muse, mutect2, varscan2
- PRDM10 | c.2798C>T p.A933V | Missense Mutation (SNP) | VAF 26/378 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.072); catalogued as rs774682934; called by muse, mutect2
- PRKCA | c.1663G>A p.V555I | Missense Mutation (SNP) | VAF 82/214 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.213); catalogued as rs1041174047, COSV101151263; called by muse, mutect2, varscan2
- PRKCA | c.1970C>T p.S657L | Missense Mutation (SNP) | VAF 57/170 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs369070488; called by muse, mutect2, varscan2
- PROCR | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.903); catalogued as rs759840671; called by muse, mutect2, varscan2
- PRODH2 | c.1425G>T p.L475= (on ENST00000301175; = p.L399= on NM_021232.2 and 3 other RefSeq transcripts) | Splice Region (SNP) | VAF 12/291 reads (4%) | catalogued as COSV56561554, COSV99995199; called by muse, mutect2
- PRPH | c.546-5G>A | Splice Region (SNP) | VAF 119/350 reads (34%) | catalogued as rs748434193; called by muse, mutect2, varscan2
- PRR5 | c.605C>T p.T202M (on ENST00000336985 / NM_181333.4; = p.T193M on NM_015366.4) | Missense Mutation (SNP) | VAF 109/259 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs769350219; called by muse, mutect2, varscan2
- PRRT4 | c.2143G>A p.D715N (on ENST00000446477 / NM_001174164.1; = p.R370Q on NM_001114726.3) | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs771704613; called by muse, mutect2, varscan2
- PRX | c.2716C>A p.P906T | Missense Mutation (SNP) | VAF 289/754 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.306); catalogued as COSV52531931; called by muse, mutect2, varscan2
- PTCH1 | c.3422C>T p.A1141V | Missense Mutation (SNP) | VAF 201/553 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as rs376844749, CM066198, COSV59469480; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTGDR2 | c.521C>T p.S174L | Missense Mutation (SNP) | VAF 122/330 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV57125058; called by muse, mutect2, varscan2
- PTGS1 | c.716G>A p.R239H | Missense Mutation (SNP) | VAF 130/361 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.456); catalogued as rs201247583, COSV56294348; called by muse, mutect2, varscan2
- PTPRG | c.1810G>A p.E604K | Missense Mutation (SNP) | VAF 78/225 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.284); catalogued as rs1433488876; called by muse, mutect2, varscan2
- PTPRK | c.3584C>T p.A1195V (on ENST00000368215 / NM_001291984.2; = p.A1196V on NM_002844.4) | Missense Mutation (SNP) | VAF 90/240 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV63902821; called by muse, mutect2, varscan2
- PTPRS | c.4642C>T p.R1548C | Missense Mutation (SNP) | VAF 54/161 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369058883; called by muse, mutect2, varscan2
- PUS7L | c.1520G>A p.R507H | Missense Mutation (SNP) | VAF 73/208 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143825055; called by muse, mutect2, varscan2
- PWWP2A | c.2074C>T p.R692C | Missense Mutation (SNP) | VAF 72/184 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs1458796633, COSV61046500; called by muse, mutect2, varscan2
- PYGB | c.1279C>T p.R427C | Missense Mutation (SNP) | VAF 88/239 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as rs759787640, COSV53818385; called by muse, mutect2, varscan2
- R3HCC1L | c.2320C>T p.R774W (on ENST00000612478 / NM_001256619.2; = p.R760W on NM_014472.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 76/254 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as rs374287974; called by muse, mutect2, varscan2
- RABEPK | c.493G>A p.V165M | Missense Mutation (SNP) | VAF 61/155 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs201854182; called by muse, mutect2, varscan2
- RAD17 | c.1252C>T p.R418W (on ENST00000380774 / NM_133339.2; = p.R407W on NM_002873.1) | Missense Mutation (SNP) | VAF 72/199 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as rs762037388; called by muse, mutect2, varscan2
- RAD21L1 | c.1445G>T p.W482L | Missense Mutation (SNP) | VAF 51/184 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.879); catalogued as COSV67881188; called by muse, mutect2, varscan2
- RASGEF1A | c.100G>A p.G34S | Missense Mutation (SNP) | VAF 106/287 reads (37%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs569953656; called by muse, mutect2, varscan2
- RASGRP2 | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 193/529 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as rs535901850; called by muse, mutect2, varscan2
- RASL10A | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.301); catalogued as rs1220391318, COSV53331291; called by muse, mutect2, varscan2
- RASL10B | c.139G>A p.V47I | Missense Mutation (SNP) | VAF 105/329 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.102); catalogued as rs587693649; called by muse, mutect2, varscan2
- RASL10B | c.338C>T p.T113M | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.387); catalogued as rs782124257; called by muse, mutect2, varscan2
- RBM33 | c.2015G>A p.R672Q | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as rs759618023, COSV56636941; called by muse, mutect2
- RBM38 | c.209A>G p.Q70R | Missense Mutation (SNP) | VAF 55/176 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.36); catalogued as rs1385754220; called by muse, mutect2, varscan2
- RBMXL3 | c.2455G>A p.E819K | Missense Mutation (SNP) | VAF 112/343 reads (33%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.031); catalogued as rs781895062; called by muse, mutect2, varscan2
- RBPMS2 | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 58/177 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.664); catalogued as rs753180915; called by muse, mutect2, varscan2
- REPIN1 | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 79/205 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs748725565, COSV68293072; called by muse, mutect2, varscan2
- RET | c.3216G>T p.E1072D | Missense Mutation (SNP) | VAF 167/494 reads (34%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.532); catalogued as COSV60702040; called by muse, mutect2, varscan2
- REXO1 | c.1003C>T p.R335W | Missense Mutation (SNP) | VAF 43/140 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as rs371943737; called by muse, mutect2, varscan2
- RFTN1 | c.1171G>A p.V391M | Missense Mutation (SNP) | VAF 73/235 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.043); catalogued as rs1192602111; called by muse, mutect2, varscan2
- RFX2 | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.03); catalogued as rs757505751, COSV57946109; called by muse, mutect2, varscan2
- RGS3 | c.596C>T p.P199L (on ENST00000350696 / NM_001282923.2; = p.P87L on NM_017790.4) | Missense Mutation (SNP) | VAF 49/175 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764353446, COSV100465428; called by muse, mutect2, varscan2
- RHBDF1 | c.2366A>G p.Y789C | Missense Mutation (SNP) | VAF 102/300 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51958840; called by muse, mutect2, varscan2
- RHOBTB2 | c.613C>T p.R205* | Nonsense Mutation (SNP) | VAF 98/323 reads (30%) | catalogued as rs773780599, COSV99310648; called by muse, mutect2, varscan2
- RHOF | c.325G>A p.V109I | Missense Mutation (SNP) | VAF 84/193 reads (44%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.981); catalogued as rs201682479; called by muse, mutect2, varscan2
- RHOT2 | c.1588G>A p.E530K | Missense Mutation (SNP) | VAF 174/502 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.356); catalogued as rs1232243985; called by muse, mutect2, varscan2
- RIMBP2 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 60/291 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs559103568; called by muse, mutect2, varscan2
- RIMBP2 | c.166C>T p.R56W | Missense Mutation (SNP) | VAF 54/158 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as rs376169658; called by muse, mutect2
- RIPOR1 | c.2471G>A p.R824H (on ENST00000379312 / NM_001193522.2; = p.R820H on NM_024519.4) | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT tolerated (0.56); PolyPhen benign (0.046); catalogued as rs138012370; called by muse, mutect2, varscan2
- RNF113B | c.107G>A p.R36H | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs776956246; called by muse, mutect2, varscan2
- RNF128 | c.514G>A p.G172S (on ENST00000255499 / NM_194463.2; = p.G146S on NM_024539.3) | Missense Mutation (SNP) | VAF 94/234 reads (40%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.633); catalogued as rs779968781; called by muse, mutect2, varscan2
- RNF157 | c.1327G>A p.V443M | Missense Mutation (SNP) | VAF 49/134 reads (37%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.048); catalogued as rs201495655, COSV53942053; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 86/256 reads (34%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RP9 | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 118/663 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.705); catalogued as rs762365872, COSV99778021; called by muse, mutect2, varscan2
- RPL10L | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 147/425 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as rs143533362; called by muse, mutect2, varscan2
- RPL10L | c.145G>A p.G49S | Missense Mutation (SNP) | VAF 171/482 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs960971618; called by muse, mutect2, varscan2
- RPS6KA4 | c.2164G>A p.V722M | Missense Mutation (SNP) | VAF 114/333 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs902255820; called by muse, mutect2, varscan2
- RPS6KL1 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 169/436 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as rs759367848, COSV100665234; called by muse, mutect2, varscan2
- RPUSD2 | c.1508G>A p.R503Q | Missense Mutation (SNP) | VAF 109/297 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.241); catalogued as rs770915258; called by muse, mutect2, varscan2
- RTCB | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 53/157 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53277150; called by muse, mutect2, varscan2
- RTTN | c.280C>T p.R94W | Missense Mutation (SNP) | VAF 91/257 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1490930098, COSV55351975; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RUBCN | c.2815C>T p.R939W | Missense Mutation (SNP) | VAF 79/220 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766142943; called by muse, mutect2, varscan2
- RUNX3 | c.880G>A p.V294M | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as rs142450822; called by muse, mutect2, varscan2
- RUVBL2 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 128/430 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs371296069; called by muse, mutect2, varscan2
- RXRB | c.1453C>T p.R485W | Missense Mutation (SNP) | VAF 68/178 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763483233, COSV59496254; called by muse, mutect2, varscan2
- RYR1 | c.9784C>T p.R3262C | Missense Mutation (SNP) | VAF 208/628 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs557030813; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR3 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 72/234 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774050928, COSV66776549; called by muse, mutect2, varscan2
- RYR3 | c.10096A>G p.I3366V (on ENST00000389232; = p.I3367V on NM_001036.6) | Missense Mutation (SNP) | VAF 105/298 reads (35%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.7); catalogued as rs199625290; called by muse, mutect2, varscan2
- SAMD9L | c.4547del p.N1516Mfs*10 | Frame Shift Del (DEL) | VAF 56/148 reads (38%) | catalogued as COSV59083791; called by mutect2, varscan2
- SASH3 | c.118G>A p.V40M | Missense Mutation (SNP) | VAF 53/179 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.889); catalogued as rs771809544, COSV63556674; called by muse, mutect2, varscan2
- SBF1 | c.5573C>T p.A1858V | Missense Mutation (SNP) | VAF 68/169 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs767601317; called by muse, mutect2, varscan2
- SCARB1 | c.1546G>A p.G516S | Missense Mutation (SNP) | VAF 149/405 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.058); catalogued as rs1046624984; called by muse, mutect2, varscan2
- SCARB1 | c.1257C>T p.S419= | Splice Region (SNP) | VAF 99/331 reads (30%) | catalogued as rs200718786; called by muse, mutect2, varscan2
- SCART1 | c.782C>T p.T261M | Missense Mutation (SNP) | VAF 60/163 reads (37%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.938); catalogued as rs762445225; called by muse, mutect2, varscan2
- SCLY | c.1115G>A p.R372Q (on ENST00000651534; = p.R364Q on NM_016510.7) | Missense Mutation (SNP) | VAF 60/204 reads (29%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs369266894; called by muse, varscan2
- SCN10A | c.3776G>A p.R1259Q | Missense Mutation (SNP) | VAF 75/222 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as rs957441210; called by muse, mutect2, varscan2
- SEC16A | c.433G>A p.G145S | Missense Mutation (SNP) | VAF 102/286 reads (36%) | SIFT tolerated (0.78); PolyPhen benign (0.031); catalogued as rs762718838; called by muse, mutect2, varscan2
- SEMA6B | c.1987G>A p.G663R | Missense Mutation (SNP) | VAF 50/118 reads (42%) | SIFT tolerated (0.44); PolyPhen benign (0.348); catalogued as rs1355448949; called by muse, mutect2, varscan2
- SETX | c.964G>A p.A322T | Missense Mutation (SNP) | VAF 138/386 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs540348550, COSV99809598; called by muse, mutect2, varscan2
- SFI1 | c.2204G>A p.R735Q (on ENST00000400288 / NM_001007467.3; = p.R704Q on NM_014775.4) | Missense Mutation (SNP) | VAF 65/189 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.638); catalogued as rs775566367; called by muse, mutect2, varscan2
- SFXN4 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 151/480 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs772872379; called by muse, mutect2, varscan2
- SHANK3 | c.3949G>A p.A1317T | Missense Mutation (SNP) | VAF 150/463 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs570447203; called by muse, mutect2, varscan2
- SHOX2 | c.477del p.F159Lfs*15 (on ENST00000441443 / NM_006884.3; = p.F183Lfs*15 on NM_003030.4) | Frame Shift Del (DEL) | VAF 159/526 reads (30%) | catalogued as COSV67463871; called by mutect2, pindel, varscan2
- SIGLEC1 | c.1832C>T p.A611V | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.578); catalogued as rs779069289; called by muse, mutect2, varscan2
- SIN3B | c.434C>T p.P145L | Missense Mutation (SNP) | VAF 101/304 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs929991049, COSV56131374; called by muse, mutect2, varscan2
- SIPA1L1 | c.3056C>T p.T1019M | Missense Mutation (SNP) | VAF 75/204 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs746877496, COSV62173017; called by muse, mutect2, varscan2
- SIPA1L3 | c.3601G>A p.G1201S | Missense Mutation (SNP) | VAF 61/160 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs775072098, COSV55919833; called by muse, mutect2, varscan2
- SIPA1L3 | c.4789G>A p.V1597I | Missense Mutation (SNP) | VAF 54/131 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs755582528; called by muse, mutect2, varscan2
- SLC12A7 | c.731C>T p.A244V | Missense Mutation (SNP) | VAF 93/260 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs374285965; called by muse, mutect2, varscan2
- SLC13A4 | c.99C>T p.S33= | Splice Region (SNP) | VAF 45/112 reads (40%) | catalogued as rs931080628; called by muse, mutect2, varscan2
- SLC15A5 | c.838G>A p.V280M | Missense Mutation (SNP) | VAF 132/395 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.274); catalogued as rs771735554; called by muse, mutect2, varscan2
- SLC16A11 | c.506C>T p.A169V (on ENST00000308009; = p.A145V on NM_153357.3) | Missense Mutation (SNP) | VAF 64/177 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.417); catalogued as rs541411157; called by muse, mutect2, varscan2
- SLC2A8 | c.708del p.I237Sfs*27 | Frame Shift Del (DEL) | VAF 30/102 reads (29%) | catalogued as rs199808560; called by mutect2, pindel
- SLC35A5 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 168/438 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs774550796, COSV53727756; called by muse, mutect2, varscan2
- SLC38A2 | c.823G>A p.V275M | Missense Mutation (SNP) | VAF 75/178 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs760082061, COSV56745277; called by muse, mutect2, varscan2
- SLC38A4 | c.1118C>T p.T373M | Missense Mutation (SNP) | VAF 116/346 reads (34%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.466); catalogued as rs147575073; called by muse, varscan2
- SLC44A2 | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 141/362 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.676); catalogued as rs768934304, COSV59837676; called by muse, mutect2, varscan2
- SLC45A4 | c.1315C>T p.R439C (on ENST00000517878 / NM_001286646.2; = p.R388C on NM_001080431.2) | Missense Mutation (SNP) | VAF 102/314 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as rs765333978; called by muse, mutect2, varscan2
- SLC4A11 | c.865C>T p.R289C | Missense Mutation (SNP) | VAF 217/658 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs185463872; called by muse, mutect2, varscan2
- SLC4A2 | c.2798G>A p.R933Q | Missense Mutation (SNP) | VAF 117/262 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52540296, COSV99880021; called by muse, mutect2, varscan2
- SLC5A6 | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 124/373 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs376846645; called by muse, mutect2, varscan2
- SLC5A7 | c.852G>T p.M284I | Missense Mutation (SNP) | VAF 75/209 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as COSV50888881, COSV99887039; called by muse, mutect2, varscan2
- SLC6A17 | c.1798G>A p.A600T | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as rs769736110; called by muse, mutect2, varscan2
- SLC6A18 | c.202G>T p.G68W | Missense Mutation (SNP) | VAF 59/223 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57254971; called by muse, mutect2, varscan2
- SLC7A3 | c.20G>A p.R7H | Missense Mutation (SNP) | VAF 43/126 reads (34%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as COSV53228370; called by muse, mutect2, varscan2
- SLCO2A1 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.553); catalogued as rs201131796, COSV100188963; called by muse, mutect2, varscan2
- SLCO2B1 | c.1106G>A p.R369H | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs141975187; called by muse, mutect2, varscan2
- SLFN14 | c.1120C>T p.R374* | Nonsense Mutation (SNP) | VAF 51/145 reads (35%) | catalogued as rs1320717886; called by muse, varscan2
- SLFN5 | c.2344C>T p.R782W | Missense Mutation (SNP) | VAF 115/327 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as rs777203753; called by muse, mutect2, varscan2
- SMARCA4 | c.4054G>A p.A1352T | Missense Mutation (SNP) | VAF 178/525 reads (34%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.536); catalogued as rs1228120902; called by muse, mutect2, varscan2
- SMARCAL1 | c.2384C>T p.S795L | Missense Mutation (SNP) | VAF 146/406 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.42); catalogued as rs1293966405; called by muse, mutect2, varscan2
- SMARCB1 | c.557C>T p.T186M (on ENST00000263121; = p.T232M on NM_003073.5) | Missense Mutation (SNP) | VAF 145/463 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.544); catalogued as rs776693680, COSV54093330, COSV54101934; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMARCC2 | c.3583del p.L1195Cfs*88 | Frame Shift Del (DEL) | VAF 16/72 reads (22%) | catalogued as rs1224281535; called by mutect2, pindel, varscan2
- SMG6 | c.3665G>A p.R1222H | Missense Mutation (SNP) | VAF 71/152 reads (47%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.972); catalogued as rs746297201, COSV99558859; called by muse, mutect2, varscan2
- SNTB1 | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 80/510 reads (16%) | SIFT tolerated (0.92); PolyPhen benign (0.007); catalogued as rs373258111; called by muse, mutect2, varscan2
- SNX27 | c.1324G>A p.V442I | Missense Mutation (SNP) | VAF 56/176 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as rs149937418; ClinVar: uncertain significance; called by muse, varscan2
- SOX15 | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0.001); catalogued as rs1410581285; called by muse, mutect2, varscan2
- SPAG9 | c.1130G>A p.R377H (on ENST00000262013 / NM_001130528.3; = p.R363H on NM_003971.6) | Missense Mutation (SNP) | VAF 56/142 reads (39%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.972); catalogued as rs752891486; called by muse, mutect2, varscan2
- SPATA13 | c.253C>T p.R85C | Missense Mutation (SNP) | VAF 61/142 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.043); catalogued as rs779348512, COSV101173143; called by muse, mutect2, varscan2
- SPATA5L1 | c.1354G>A p.V452I | Missense Mutation (SNP) | VAF 64/173 reads (37%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs373265646, COSV59745536, COSV59745623; called by muse, mutect2, varscan2
- SPECC1L | c.190G>A p.G64R | Missense Mutation (SNP) | VAF 150/446 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.669); catalogued as rs548017612, COSV58660795; called by muse, mutect2, varscan2
- SPEN | c.2531G>A p.R844Q | Missense Mutation (SNP) | VAF 118/348 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.644); catalogued as rs776660027, COSV65365417; called by muse, mutect2, varscan2
- SPTAN1 | c.1066C>T p.R356W | Missense Mutation (SNP) | VAF 211/621 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs370695453; ClinVar: likely benign; called by muse, mutect2, varscan2
- SPTBN2 | c.2996G>A p.R999H | Missense Mutation (SNP) | VAF 180/521 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs769417045; called by muse, mutect2, varscan2
- SRBD1 | c.1610G>A p.R537H | Missense Mutation (SNP) | VAF 80/283 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as rs376984926; called by muse, mutect2, varscan2
- SRCAP | c.550C>T p.R184W | Missense Mutation (SNP) | VAF 131/408 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs778348276, COSV52672270; called by muse, mutect2, varscan2
- SRL | c.1216G>A p.G406S | Missense Mutation (SNP) | VAF 90/253 reads (36%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.899); catalogued as rs373808257; called by muse, mutect2, varscan2
- SRRT | c.1285G>A p.A429T | Missense Mutation (SNP) | VAF 52/148 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as rs1164234590, COSV53819263; called by muse, mutect2, varscan2
- STAC | c.502C>T p.R168W | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751004980, COSV56206169; called by muse, mutect2, varscan2
- STARD9 | c.12808C>T p.R4270* | Nonsense Mutation (SNP) | VAF 117/288 reads (41%) | catalogued as rs1031966572; called by muse, varscan2
- STKLD1 | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 58/154 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as rs374609912; called by muse, mutect2, varscan2
- STOML2 | c.776G>A p.R259Q | Missense Mutation (SNP) | VAF 73/214 reads (34%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs201944176, COSV53055689; called by muse, mutect2, varscan2
- STON2 | c.2246C>T p.T749M (on ENST00000649389 / NM_001366849.2; = p.T692M on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 138/427 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs201379766; called by muse, mutect2, varscan2
- STRAP | c.499C>T p.R167* | Nonsense Mutation (SNP) | VAF 56/199 reads (28%) | catalogued as COSV50308761; called by muse, mutect2, varscan2
- STX11 | c.110C>T p.T37M | Missense Mutation (SNP) | VAF 147/460 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.917); catalogued as rs771687230, CD078721, COSV62449212; called by muse, mutect2, varscan2
- SUPT3H | c.296G>A p.R99H (on ENST00000371460 / NM_181356.3; = p.R88H on NM_003599.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 68/190 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs150635035; called by muse, mutect2, varscan2
- SUV39H2 | c.996+1G>A p.X332_splice (on ENST00000354919 / NM_001193424.2; = p.X272_splice on NM_024670.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 50/147 reads (34%) | catalogued as COSV57953728; called by muse, mutect2
- SVEP1 | c.5953G>A p.V1985I | Missense Mutation (SNP) | VAF 59/145 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.112); catalogued as rs373901354; called by muse, mutect2, varscan2
- SYCP2 | c.3944A>G p.K1315R | Missense Mutation (SNP) | VAF 103/255 reads (40%) | SIFT tolerated (0.85); PolyPhen benign (0.009); catalogued as COSV62767200; called by muse, mutect2, varscan2
- SYCP2 | c.1370G>A p.S457N | Missense Mutation (SNP) | VAF 82/238 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV100698024; called by muse, varscan2
- SYNE1 | c.22936G>A p.E7646K (on ENST00000367255 / NM_182961.4; = p.E7575K on NM_033071.3) | Missense Mutation (SNP) | VAF 128/331 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.643); catalogued as rs570265411, COSV54898590; called by muse, mutect2, varscan2
- SYNE1 | c.10259C>T p.A3420V (on ENST00000367255 / NM_182961.4; = p.A3427V on NM_033071.3) | Missense Mutation (SNP) | VAF 125/340 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.114); catalogued as rs748911036, COSV55053698; called by muse, mutect2, varscan2
- SYNGAP1 | c.1066C>T p.R356C | Missense Mutation (SNP) | VAF 79/222 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs144778033; ClinVar: likely benign; called by muse, mutect2, varscan2
- SYNJ1 | c.3379G>A p.A1127T | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs1250040982; called by muse, mutect2, varscan2
- SYNJ1 | c.2173G>A p.V725I | Missense Mutation (SNP) | VAF 69/209 reads (33%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.997); catalogued as rs377592740; called by muse, mutect2, varscan2
- SYPL2 | c.746A>G p.D249G | Missense Mutation (SNP) | VAF 96/283 reads (34%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs759565466; called by muse, mutect2, varscan2
- SYT6 | c.745C>T p.R249C (on ENST00000610222 / NM_001366225.1; = p.R164C on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 196/532 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as rs558921980, COSV101059839, COSV65772455; called by muse, mutect2, varscan2
- SYVN1 | c.1508G>A p.R503Q (on ENST00000377190 / NM_172230.3; = p.R502Q on NM_032431.3) | Missense Mutation (SNP) | VAF 110/348 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs763524114, COSV53694611, COSV53696147; called by muse, mutect2, varscan2
- TAF1C | c.1073C>T p.S358L | Missense Mutation (SNP) | VAF 117/382 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs754084058, COSV58985618; called by muse, mutect2, varscan2
- TARDBP | c.589C>T p.R197C | Missense Mutation (SNP) | VAF 176/486 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.11); catalogued as COSV53570106; called by muse, mutect2, varscan2
- TAT | c.58G>A p.V20M | Missense Mutation (SNP) | VAF 190/521 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.022); catalogued as rs1313615595, COSV63532944; called by muse, mutect2, varscan2
- TBC1D16 | c.1189G>A p.G397S | Missense Mutation (SNP) | VAF 63/176 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs375899999; called by muse, mutect2, varscan2
- TBL3 | c.2002C>T p.R668W | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs762597435, COSV60342003; called by muse, mutect2, varscan2
- TCHH | c.4814G>A p.R1605H | Missense Mutation (SNP) | VAF 173/479 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.165); catalogued as rs763165126, COSV64275407; called by muse, mutect2, varscan2
- TDRD6 | c.182C>T p.A61V | Missense Mutation (SNP) | VAF 59/161 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.37); catalogued as COSV60175947; called by muse, mutect2, varscan2
- TEAD3 | c.295C>T p.R99W | Missense Mutation (SNP) | VAF 107/372 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as COSV100132400; called by muse, mutect2, varscan2
- TEKT2 | c.949C>T p.R317W | Missense Mutation (SNP) | VAF 174/527 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749734626; called by muse, mutect2, varscan2
- TET1 | c.4595G>A p.R1532Q | Missense Mutation (SNP) | VAF 102/285 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.053); catalogued as rs780172713, COSV65382560; called by muse, mutect2, varscan2
- TEX13C | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 153/440 reads (35%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.996); catalogued as rs1006905046; called by muse, mutect2, varscan2
- TFDP1 | c.499C>T p.R167W | Missense Mutation (SNP) | VAF 57/144 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100945867; called by muse, mutect2, varscan2
- TG | c.4852G>A p.V1618M | Missense Mutation (SNP) | VAF 154/466 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.121); catalogued as rs114101452; called by muse, mutect2, varscan2
- TGFB1 | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 156/472 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as rs1195992341; called by muse, mutect2, varscan2
- THAP9 | c.793C>T p.R265* | Nonsense Mutation (SNP) | VAF 23/58 reads (40%) | catalogued as rs1303634741; called by muse, mutect2
- THBS2 | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 78/237 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751099158; called by muse, mutect2, varscan2
- THNSL2 | c.860G>A p.R287H | Missense Mutation (SNP) | VAF 35/152 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs755201587, COSV59082444; called by muse, mutect2
- THPO | c.776G>A p.R259H (on ENST00000649095 / NM_001290003.1; = p.R119H on NM_000460.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 109/300 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as rs143216798, COSV52617285; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- THRA | c.430C>T p.R144W | Missense Mutation (SNP) | VAF 91/271 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1314797277; called by muse, mutect2, varscan2
- TIMM21 | c.670C>T p.R224* | Nonsense Mutation (SNP) | VAF 57/189 reads (30%) | catalogued as rs774139287, COSV50054289; called by muse, mutect2, varscan2
- TLN2 | c.6827G>A p.R2276Q | Missense Mutation (SNP) | VAF 104/280 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs781390797; called by muse, mutect2, varscan2
- TLX1 | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 79/225 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100930105; called by muse, mutect2, varscan2
- TMEM129 | c.451C>T p.R151W | Missense Mutation (SNP) | VAF 128/309 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as rs776853832; called by muse, mutect2, varscan2
- TMEM204 | c.31G>A p.V11M | Missense Mutation (SNP) | VAF 136/393 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); catalogued as rs764949974, COSV54153008; called by muse, mutect2, varscan2
- TMEM86B | c.169G>A p.V57I | Missense Mutation (SNP) | VAF 187/516 reads (36%) | SIFT tolerated (0.92); PolyPhen benign (0.018); catalogued as rs191683509, COSV100497634; called by muse, mutect2, varscan2
- TNFRSF25 | c.1228C>T p.R410C | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747187606; called by muse, mutect2, varscan2
- TNKS1BP1 | c.1630C>T p.Q544* | Nonsense Mutation (SNP) | VAF 91/260 reads (35%) | catalogued as rs1400080424; called by muse, mutect2, varscan2
- TNP1 | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 192/569 reads (34%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.082); catalogued as rs764002498, COSV52697005; called by muse, mutect2, varscan2
- TNRC6C | c.1837A>G p.K613E | Missense Mutation (SNP) | VAF 106/284 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); catalogued as rs778201969, COSV56951956; called by mutect2, varscan2
- TNS3 | c.1223G>A p.R408H | Missense Mutation (SNP) | VAF 65/196 reads (33%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs746193332, COSV60801269; called by muse, mutect2, varscan2
- TOGARAM2 | c.830G>A p.R277Q | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.138); catalogued as rs576185513; called by muse, mutect2, varscan2
- TOM1L2 | c.409G>A p.V137I (on ENST00000379504 / NM_001350333.2; = p.V87I on NM_001033551.3) | Missense Mutation (SNP) | VAF 84/284 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs200120270; called by muse, mutect2, varscan2
- TPCN2 | c.2111G>A p.R704H | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs773649037, COSV53727070; called by muse, mutect2, varscan2
- TPO | c.347C>T p.T116M | Missense Mutation (SNP) | VAF 100/336 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.799); catalogued as rs751244187, COSV61108938; called by muse, mutect2, varscan2
- TRAF5 | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 78/230 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs576776178, COSV54821156; called by muse, mutect2, varscan2
- TRARG1 | c.508G>A p.V170I | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT tolerated (0.53); PolyPhen benign (0.017); catalogued as rs1378961733, COSV61562612; called by muse, mutect2, varscan2
- TRIM2 | c.425C>T p.T142M (on ENST00000437508; = p.T169M on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.895); catalogued as rs762398531; called by muse, mutect2, varscan2
- TRIM3 | c.1058G>A p.R353Q | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs757648121; called by muse, mutect2, varscan2
- TRIM3 | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 80/235 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as rs146379181; called by muse, mutect2, varscan2
- TRIM39-RPP21 | c.1363G>A p.G455R | Missense Mutation (SNP) | VAF 73/258 reads (28%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs554843005; called by muse, mutect2, varscan2
- TRIM77 | c.496G>A p.G166R | Missense Mutation (SNP) | VAF 80/208 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs747086502, COSV68066746; called by muse, mutect2, varscan2
- TRPC7 | c.2422G>A p.E808K | Missense Mutation (SNP) | VAF 70/166 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as rs767313749; called by muse, mutect2
- TRPM2 | c.1228G>C p.V410L | Missense Mutation (SNP) | VAF 66/188 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.038); catalogued as rs758657148, COSV100308737; called by muse, mutect2, varscan2
- TRPM4 | c.2953G>A p.V985M | Missense Mutation (SNP) | VAF 91/224 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.323); catalogued as rs930812883, COSV53259986; called by muse, mutect2, varscan2
- TRPV4 | c.1405G>A p.V469I | Missense Mutation (SNP) | VAF 162/474 reads (34%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.99); catalogued as rs369637458; called by muse, varscan2
- TTC22 | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs762407457, COSV64881765; called by muse, mutect2, varscan2
- TTC33 | c.610T>G p.Y204D | Missense Mutation (SNP) | VAF 101/269 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV61802551; called by muse, mutect2, varscan2
- TTLL4 | c.3484C>T p.P1162S | Missense Mutation (SNP) | VAF 174/501 reads (35%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as rs1433188510; called by muse, mutect2, varscan2
- TTN | c.31733T>C p.V10578A (on ENST00000591111; = p.V9651A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 93/254 reads (37%) | PolyPhen benign (0.001); catalogued as rs779091157, COSV60194176; called by muse, mutect2, varscan2
- TTN | c.23066G>A p.C7689Y (on ENST00000591111; = p.C6762Y on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/162 reads (9%) | PolyPhen probably damaging (0.998); catalogued as rs764282358; ClinVar: uncertain significance; called by muse, mutect2
- TXLNB | c.181C>T p.R61* | Nonsense Mutation (SNP) | VAF 172/542 reads (32%) | catalogued as rs751023549; called by muse, mutect2, varscan2
- UBAP1L | c.859C>T p.R287* | Nonsense Mutation (SNP) | VAF 101/259 reads (39%) | catalogued as rs764531829; called by muse, mutect2, varscan2
- UBQLN2 | c.44G>A p.R15H | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.679); catalogued as COSV100592772; called by muse, mutect2, varscan2
- UBR4 | c.2326G>A p.V776I | Missense Mutation (SNP) | VAF 106/292 reads (36%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.796); catalogued as rs1192691217; called by muse, varscan2
1,005 further variants in this file (405 protein-altering or splice-affecting, 419 silent, 181 other) are not listed here.
